Somatic mutation profile of tumor specimen 1105241 (aliquot 7316UP-219-1105241) from CPTAC case C243909, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS.
Specimen 1105241: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Cerebrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 40b93d12-59fc-4855-8f5b-cdc74df125a4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105279 (Blood Derived Normal), aliquot 7316UP-219-1105279; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d89213b7-9640-4e13-baa7-49c9a0f78ce4

The open-access MAF lists 908 somatic variants for this specimen: 603 protein-altering or splice-affecting, 193 silent, 112 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 499, Silent 193, Nonsense Mutation 55, Intron 55, RNA 21, Frame Shift Del 17, 5'UTR 17, Splice Site 12, 3'UTR 11, Splice Region 8, Frame Shift Ins 6, 5'Flank 5.

Variants (750 of 908; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.311C>T p.P104L | Missense Mutation (SNP) | VAF 16/38 reads (42%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs863225060, COSV55878075, COSV55925758; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TMEM67 | c.244C>T p.P82S | Missense Mutation (SNP) | VAF 115/195 reads (59%) | SIFT tolerated (0.1); PolyPhen benign (0.034); catalogued as rs762543032, CM100393; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.403T>G p.C135G | Missense Mutation (SNP) | VAF 296/303 reads (98%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519975, COSV52674321, COSV52706302, COSV52827707; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- A1CF | c.1096G>T p.G366* | Nonsense Mutation (SNP) | VAF 108/236 reads (46%) | catalogued as COSV50958623; called by muse, mutect2, varscan2
- ADAM12 | c.2005-1G>T p.X669_splice | Splice Site (SNP) | VAF 13/99 reads (13%) | catalogued as COSV100901300; called by muse, mutect2, varscan2
- ADAMTS14 | c.2123G>T p.G708V | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64600390; called by muse, mutect2
- ADAMTS2 | c.2486C>G p.S829* | Nonsense Mutation (SNP) | VAF 89/289 reads (31%) | catalogued as COSV52370863, COSV52383930; called by muse, mutect2, varscan2
- AGTPBP1 | c.1369G>A p.V457I (on ENST00000357081 / NM_001330701.2; = p.V417I on NM_015239.2) | Missense Mutation (SNP) | VAF 39/72 reads (54%) | SIFT tolerated (0.2); PolyPhen benign (0.019); catalogued as rs745710606; called by muse, mutect2, varscan2
- ANK3 | c.12236G>A p.R4079K | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); catalogued as COSV99781711; called by muse, varscan2
- ANO7 | c.962C>A p.A321E (on ENST00000274979; = p.A267E on NM_001370694.2) | Missense Mutation (SNP) | VAF 67/169 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs375507696; called by muse, mutect2, varscan2
- ANXA13 | c.457G>C p.V153L | Missense Mutation (SNP) | VAF 292/401 reads (73%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as rs1409407846; called by muse, mutect2, varscan2
- APOB | c.2329C>A p.L777I | Missense Mutation (SNP) | VAF 114/163 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99267907; called by muse, mutect2, varscan2
- ARAP3 | c.214G>T p.D72Y | Missense Mutation (SNP) | VAF 67/119 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); catalogued as rs1186879516; called by muse, mutect2, varscan2
- ARFGAP3 | c.351C>G p.I117M | Missense Mutation (SNP) | VAF 60/224 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.896); catalogued as COSV54311444; called by muse, mutect2, varscan2
- ARHGAP12 | c.1900C>T p.L634F | Missense Mutation (SNP) | VAF 61/157 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60961844, COSV60963784; called by muse, mutect2, varscan2
- ARHGAP22 | c.440C>T p.P147L | Missense Mutation (SNP) | VAF 40/326 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs201381170; called by muse, mutect2, varscan2
- ARHGAP9 | c.931C>T p.R311* | Nonsense Mutation (SNP) | VAF 84/890 reads (9%) | catalogued as rs760103624, COSV57364355; called by muse, mutect2
- ARHGEF15 | c.2113C>T p.P705S | Missense Mutation (SNP) | VAF 46/394 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.066); catalogued as rs750498025; called by muse, mutect2, varscan2
- ASTN1 | c.1124G>T p.G375V | Missense Mutation (SNP) | VAF 39/86 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56072577; called by muse, mutect2, varscan2
- BRWD3 | c.3224C>A p.P1075Q | Missense Mutation (SNP) | VAF 44/150 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.04); catalogued as rs1051653380; called by muse, mutect2, varscan2
- C20orf144 | c.304C>T p.Q102* | Nonsense Mutation (SNP) | VAF 260/520 reads (50%) | catalogued as rs1183825290; called by muse, mutect2, varscan2
- C9orf131 | c.1454T>C p.M485T | Missense Mutation (SNP) | VAF 47/170 reads (28%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as rs1380081534; called by muse, mutect2, varscan2
- CACNA1G | c.868G>A p.G290R | Missense Mutation (SNP) | VAF 72/227 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.294); catalogued as rs766099998; called by muse, mutect2, varscan2
- CACNA2D2 | c.2869C>T p.R957W (on ENST00000479441 / NM_001174051.3; = p.R950W on NM_006030.4) | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1209696501, COSV99817832; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CAPN15 | c.2941G>T p.G981C | Missense Mutation (SNP) | VAF 34/50 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54836374, COSV99562579; called by muse, mutect2, varscan2
- CD163 | c.3131G>A p.R1044H | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs747001854; called by muse, mutect2, varscan2
- CDC40 | c.778G>A p.D260N | Missense Mutation (SNP) | VAF 65/203 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.688); catalogued as rs890438403; called by muse, mutect2, varscan2
- CDH9 | c.1061C>A p.P354H | Missense Mutation (SNP) | VAF 36/331 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.563); catalogued as COSV50300303; called by muse, mutect2, varscan2
- CDK1 | c.107G>T p.R36I | Missense Mutation (SNP) | VAF 26/226 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100358872; called by muse, mutect2, varscan2
- CDX4 | c.461A>T p.H154L | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.303); catalogued as COSV100999147; called by muse, mutect2, varscan2
- CEP85 | c.727A>G p.N243D | Missense Mutation (SNP) | VAF 78/128 reads (61%) | SIFT tolerated (0.48); PolyPhen benign (0.022); catalogued as rs150424067; called by muse, mutect2, varscan2
- CHAF1A | c.1671G>A p.M557I | Missense Mutation (SNP) | VAF 43/160 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.729); catalogued as rs764009577; called by muse, mutect2, varscan2
- CNMD | c.905G>C p.G302A | Missense Mutation (SNP) | VAF 39/211 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1488046150; called by muse, mutect2, varscan2
- COL22A1 | c.3188G>T p.G1063V | Missense Mutation (SNP) | VAF 98/170 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as COSV57364241; called by muse, mutect2, varscan2
- COL6A3 | c.4108G>A p.A1370T | Missense Mutation (SNP) | VAF 77/743 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.793); catalogued as rs372234605, COSV55085755; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CPLANE1 | c.7838C>G p.S2613* | Nonsense Mutation (SNP) | VAF 29/354 reads (8%) | catalogued as COSV99949726; called by muse, mutect2
- CSMD1 | c.9653C>A p.P3218Q (on ENST00000520002; = p.P3217Q on NM_033225.6) | Missense Mutation (SNP) | VAF 17/141 reads (12%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.985); catalogued as COSV59306150; called by muse, mutect2, varscan2
- CSMD1 | c.3701G>T p.G1234V (on ENST00000520002; = p.G1233V on NM_033225.6) | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as rs763737608; called by muse, mutect2, varscan2
- CSMD3 | c.9299G>T p.G3100V (on ENST00000297405 / NM_001363185.1; = p.G2931V on NM_052900.3) | Missense Mutation (SNP) | VAF 441/820 reads (54%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV52184151; called by muse, mutect2, varscan2
- CSMD3 | c.1222C>A p.P408T | Missense Mutation (SNP) | VAF 351/476 reads (74%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.023); catalogued as COSV52092277, COSV52126694; called by muse, mutect2, varscan2
- DAAM1 | c.560C>T p.A187V | Missense Mutation (SNP) | VAF 37/419 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62834150; called by muse, mutect2
- DAGLB | c.718G>A p.A240T | Missense Mutation (SNP) | VAF 37/149 reads (25%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs755797799; called by muse, mutect2, varscan2
- DCDC1 | c.1633C>A p.P545T | Missense Mutation (SNP) | VAF 46/103 reads (45%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.956); catalogued as rs566810543; called by muse, mutect2, varscan2
- DES | c.1147C>A p.R383S | Missense Mutation (SNP) | VAF 252/485 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV64660959; called by muse, mutect2, varscan2
- DGKQ | c.2369C>G p.S790C | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.873); catalogued as COSV99298305; called by muse, mutect2, varscan2
- DMD | c.2821C>T p.P941S | Missense Mutation (SNP) | VAF 166/392 reads (42%) | SIFT tolerated (0.38); PolyPhen benign (0.014); catalogued as rs1477425663; called by muse, mutect2, varscan2
- DNAH8 | c.1148C>T p.S383L | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.073); catalogued as COSV59451127; called by muse, mutect2
- DST | c.2437G>A p.D813N (on ENST00000361203 / NM_001374722.1; = p.D487N on NM_001723.6) | Missense Mutation (SNP) | VAF 115/288 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs367639314; called by muse, mutect2, varscan2
- DYNC1H1 | c.13349C>T p.T4450M | Missense Mutation (SNP) | VAF 66/294 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.695); catalogued as rs146087540; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DYNC1I1 | c.1609G>A p.D537N | Missense Mutation (SNP) | VAF 47/264 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.84); catalogued as COSV100268810, COSV61468022; called by muse, mutect2, varscan2
- EMILIN2 | c.346G>A p.G116R | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.356); catalogued as COSV54423432; called by muse, mutect2, varscan2
- ENAH | c.325G>C p.E109Q | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.676); catalogued as COSV52869089; called by muse, mutect2
- EOMES | c.1403G>T p.G468V | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.079); catalogued as rs536220570; called by muse, mutect2, varscan2
- EPHA4 | c.2197G>T p.G733W | Missense Mutation (SNP) | VAF 261/501 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56037210; called by muse, mutect2, varscan2
- ERGIC2 | c.617T>C p.V206A | Missense Mutation (SNP) | VAF 58/115 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.26); catalogued as rs774859065; called by muse, mutect2, varscan2
- ERN1 | c.2668A>T p.R890W | Missense Mutation (SNP) | VAF 25/215 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101458406; called by muse, mutect2, varscan2
- ETS2 | c.1189G>A p.D397N | Missense Mutation (SNP) | VAF 41/88 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as COSV62872572; called by muse, mutect2, varscan2
- EYS | c.3684G>A p.M1228I | Missense Mutation (SNP) | VAF 89/228 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV58203363; called by muse, mutect2, varscan2
- F7 | c.919C>T p.R307C | Missense Mutation (SNP) | VAF 164/256 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs147680958, CM001151; called by muse, mutect2, varscan2
- FAM184B | c.371C>A p.S124* | Nonsense Mutation (SNP) | VAF 36/58 reads (62%) | catalogued as rs1188972903, COSV53957258; called by muse, mutect2, varscan2
- FAM47B | c.1367G>A p.R456H | Missense Mutation (SNP) | VAF 49/423 reads (12%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs759914400; called by muse, mutect2, varscan2
- FARP2 | c.2548G>A p.A850T | Missense Mutation (SNP) | VAF 53/314 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.058); catalogued as rs777762724; called by muse, mutect2, varscan2
- FGA | c.1541C>G p.P514R | Missense Mutation (SNP) | VAF 39/76 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.067); catalogued as rs746087673, CD035514, COSV57393503, COSV57402272; called by muse, mutect2, varscan2
- FLII | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 33/197 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV58943841; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.1644G>T p.K548N | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.786); catalogued as COSV100438086; called by muse, mutect2, varscan2
- FRY | c.1840C>T p.R614* | Nonsense Mutation (SNP) | VAF 50/246 reads (20%) | catalogued as rs776773297, COSV66567927; called by muse, mutect2, varscan2
- FSIP2 | c.15454G>A p.E5152K | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.018); catalogued as rs1197100532; called by muse, mutect2, varscan2
- GABPA | c.1088G>T p.R363L | Missense Mutation (SNP) | VAF 60/61 reads (98%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV61396593; called by muse, mutect2, varscan2
- GABRA5 | c.1370G>T p.G457V | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.558); catalogued as COSV59479388; called by muse, mutect2, varscan2
- GGPS1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 66/105 reads (63%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.38); catalogued as COSV51396852; called by muse, mutect2, varscan2
- GPM6A | c.361A>G p.T121A | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT tolerated (0.67); PolyPhen benign (0.012); catalogued as rs1345183983; called by muse, mutect2, varscan2
- GPRASP1 | c.1168C>T p.R390* | Nonsense Mutation (SNP) | VAF 33/104 reads (32%) | catalogued as rs1294027624, COSV100851087; called by muse, mutect2, varscan2
- GRM8 | c.2420C>T p.S807L | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.345); catalogued as COSV100283592; called by muse, mutect2, varscan2
- H2BW1 | c.235G>A p.D79N | Missense Mutation (SNP) | VAF 16/204 reads (8%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.995); catalogued as rs1264516494; called by muse, mutect2
- HCST | c.227G>T p.R76L | Missense Mutation (SNP) | VAF 134/137 reads (98%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.072); catalogued as rs777647806; called by muse, mutect2, varscan2
- HDAC9 | c.2035C>A p.R679= | Splice Region (SNP) | VAF 114/117 reads (97%) | catalogued as COSV67786067; called by muse, mutect2, varscan2
- HERC2 | c.7361C>T p.S2454L | Missense Mutation (SNP) | VAF 30/185 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.276); catalogued as rs879255382, COSV55350151; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HS3ST6 | c.920G>A p.R307Q | Missense Mutation (SNP) | VAF 49/135 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.818); catalogued as rs567994936; called by muse, mutect2, varscan2
- HSPD1 | c.106G>T p.A36S | Missense Mutation (SNP) | VAF 24/348 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.479); catalogued as COSV52099150, COSV52099158; called by muse, mutect2
- IL11RA | c.709C>T p.R237* | Nonsense Mutation (SNP) | VAF 93/258 reads (36%) | catalogued as rs775348905; called by muse, mutect2, varscan2
- IL27RA | c.1514G>A p.R505Q | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs994827825, COSV54599596; called by muse, mutect2, varscan2
- INSYN2B | c.239C>A p.S80* | Nonsense Mutation (SNP) | VAF 18/24 reads (75%) | catalogued as COSV99911494; called by muse, mutect2, varscan2
- IPP | c.55C>T p.H19Y | Missense Mutation (SNP) | VAF 52/128 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.049); catalogued as rs780057516; called by muse, mutect2, varscan2
- ITGA6 | c.1636G>T p.A546S (on ENST00000442250; = p.A507S on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/297 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.253); catalogued as rs771764369; called by muse, mutect2
- ITGBL1 | c.506G>T p.G169V | Missense Mutation (SNP) | VAF 77/127 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); catalogued as COSV66009702; called by muse, mutect2, varscan2
- IVL | c.94G>T p.E32* | Nonsense Mutation (SNP) | VAF 45/345 reads (13%) | catalogued as COSV64217090; called by muse, mutect2, varscan2
- KALRN | c.3252C>A p.N1084K | Missense Mutation (SNP) | VAF 54/91 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV53785502; called by muse, mutect2, varscan2
- KCNQ3 | c.2207C>T p.S736F | Missense Mutation (SNP) | VAF 53/548 reads (10%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.548); catalogued as rs1172699877; called by muse, mutect2
- KEAP1 | c.830C>A p.T277K | Missense Mutation (SNP) | VAF 266/274 reads (97%) | SIFT deleterious (0.02); PolyPhen benign (0.263); catalogued as COSV50262958; called by muse, mutect2, varscan2
- KLHL29 | c.52C>T p.R18C | Missense Mutation (SNP) | VAF 51/208 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs771088004; called by muse, mutect2, varscan2
- KLRC2 | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 29/171 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.106); catalogued as rs1401787503, COSV67900231; called by muse, mutect2, varscan2
- KRT84 | c.255G>A p.M85I | Missense Mutation (SNP) | VAF 520/678 reads (77%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs1475558984; called by muse, mutect2, varscan2
- LAMA5 | c.4299C>G p.N1433K | Missense Mutation (SNP) | VAF 19/212 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs576766054, COSV99439506; called by muse, mutect2
- LPAR3 | c.310C>T p.L104F | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.077); catalogued as COSV65452722; called by muse, mutect2, varscan2
- LRCH1 | c.1859G>A p.R620H | Missense Mutation (SNP) | VAF 73/99 reads (74%) | SIFT tolerated (0.06); PolyPhen benign (0.122); catalogued as rs1209521446, COSV60844120; called by muse, mutect2, varscan2
- LRRC7 | c.3160C>A p.P1054T (on ENST00000651989 / NM_001370785.2; = p.P1021T on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 58/150 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as rs1428457255, COSV50608408; called by muse, mutect2, varscan2
- LRRFIP1 | c.1147G>A p.E383K (on ENST00000392000 / NM_001137552.2; = p.E359K on NM_004735.4) | Missense Mutation (SNP) | VAF 34/402 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.019); catalogued as rs147303790; called by muse, mutect2
- MAGEB18 | c.76G>A p.G26R | Missense Mutation (SNP) | VAF 15/289 reads (5%) | SIFT tolerated (0.52); PolyPhen benign (0.015); catalogued as COSV57464664, COSV57465471; called by muse, mutect2
- MALRD1 | c.6098G>T p.G2033V | Missense Mutation (SNP) | VAF 42/197 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs1423736208; called by muse, mutect2, varscan2
- MARCKS | c.59G>T p.G20V | Missense Mutation (SNP) | VAF 227/382 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV100893018; called by muse, mutect2, varscan2
- MAST3 | c.3649C>T p.R1217W | Missense Mutation (SNP) | VAF 34/249 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.17); catalogued as rs753197504; called by muse, mutect2, varscan2
- MAT2B | c.353G>T p.G118V | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.832); catalogued as COSV55201041; called by muse, mutect2, varscan2
- MC3R | c.242C>T p.A81V | Missense Mutation (SNP) | VAF 55/359 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); catalogued as COSV54763127; called by muse, mutect2, varscan2
- MGAT2 | c.322G>C p.D108H | Missense Mutation (SNP) | VAF 24/363 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as rs1476271337, COSV53567037; called by muse, mutect2
- MIPOL1 | c.606G>C p.M202I | Missense Mutation (SNP) | VAF 140/204 reads (69%) | SIFT tolerated (0.07); PolyPhen benign (0.033); catalogued as COSV59390976; called by muse, mutect2, varscan2
- MMP2 | c.1229G>T p.G410V | Missense Mutation (SNP) | VAF 124/357 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM161173; called by muse, mutect2, varscan2
- MPP7 | c.1204C>T p.H402Y | Missense Mutation (SNP) | VAF 170/330 reads (52%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.55); catalogued as rs762252605, COSV61739431; called by muse, mutect2, varscan2
- MTUS2 | c.1358T>C p.I453T | Missense Mutation (SNP) | VAF 41/189 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs1003183536; called by muse, mutect2, varscan2
- MUC17 | c.9346C>A p.P3116T | Missense Mutation (SNP) | VAF 42/170 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0.341); catalogued as rs562321094; called by muse, mutect2, varscan2
- MUC22 | c.509C>G p.S170C | Missense Mutation (SNP) | VAF 30/214 reads (14%) | SIFT deleterious, low confidence (0.01); catalogued as rs1225649659, COSV73736210; called by muse, mutect2, varscan2
- N6AMT1 | c.507C>G p.F169L | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as rs757481872; called by muse, mutect2, varscan2
- NAV2 | c.1771G>A p.G591R (on ENST00000396087 / NM_001244963.2; = p.G568R on NM_145117.5) | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766703127; called by muse, mutect2, varscan2
- NBEA | c.4375G>C p.E1459Q | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV59765586; called by muse, mutect2, varscan2
- NEFL | c.1154A>T p.E385V | Missense Mutation (SNP) | VAF 41/273 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1563251398, COSV99648163; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NHSL2 | c.1702G>C p.D568H (on ENST00000510661; = p.D934H on NM_001013627.2) | Missense Mutation (SNP) | VAF 36/269 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.437); catalogued as rs1237800923, COSV101029883; called by muse, mutect2, varscan2
- NLRP1 | c.127G>A p.A43T | Missense Mutation (SNP) | VAF 661/783 reads (84%) | SIFT tolerated (0.1); PolyPhen benign (0.066); catalogued as rs145709003; called by mutect2, varscan2
- NLRP13 | c.1133C>T p.P378L | Missense Mutation (SNP) | VAF 40/129 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1237283312, COSV61624677; called by muse, mutect2, varscan2
- NLRP5 | c.838C>T p.R280C | Missense Mutation (SNP) | VAF 43/137 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as rs372305298, COSV66768008; called by muse, mutect2, varscan2
- NOP58 | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.098); catalogued as COSV51895561; called by muse, varscan2
- NPBWR2 | c.806G>T p.C269F | Missense Mutation (SNP) | VAF 41/176 reads (23%) | SIFT tolerated (0.53); PolyPhen benign (0.14); catalogued as COSV63900403; called by muse, mutect2, varscan2
- NPY1R | c.1022G>T p.R341L | Missense Mutation (SNP) | VAF 77/173 reads (45%) | SIFT tolerated (0.65); PolyPhen benign (0.015); catalogued as COSV56714298, COSV56715481; called by muse, mutect2, varscan2
- NRBP1 | c.1268C>G p.P423R | Missense Mutation (SNP) | VAF 195/287 reads (68%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as COSV51993925; called by muse, mutect2, varscan2
- NRK | c.398C>G p.A133G | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.92); PolyPhen possibly damaging (0.514); catalogued as COSV54590582; called by muse, mutect2, varscan2
- NTRK1 | c.354T>A p.S118R | Missense Mutation (SNP) | VAF 210/790 reads (27%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as CD087748; called by muse, mutect2, varscan2
- OLFM4 | c.223G>T p.G75C | Missense Mutation (SNP) | VAF 33/138 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99524180; called by muse, mutect2, varscan2
- OLFML2A | c.1279G>C p.D427H | Missense Mutation (SNP) | VAF 73/164 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs202197796; called by muse, mutect2, varscan2
- OR14A16 | c.405C>A p.D135E | Missense Mutation (SNP) | VAF 104/158 reads (66%) | SIFT deleterious (0.01); PolyPhen benign (0.109); catalogued as rs1374004830; called by muse, mutect2, varscan2
- OR2T33 | c.807C>A p.D269E | Missense Mutation (SNP) | VAF 264/436 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV58815134; called by muse, mutect2, varscan2
- OR4A16 | c.855C>A p.Y285* | Nonsense Mutation (SNP) | VAF 110/111 reads (99%) | catalogued as COSV59045243, COSV59045505; called by muse, mutect2, varscan2
- OR51B2 | c.413G>A p.R138K | Missense Mutation (SNP) | VAF 113/114 reads (99%) | SIFT tolerated (0.22); PolyPhen benign (0.029); catalogued as rs758948105; called by muse, mutect2, varscan2
- OXA1L | c.529G>A p.G177R (on ENST00000285848; = p.G117R on NM_005015.5) | Missense Mutation (SNP) | VAF 46/279 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53537431; called by muse, mutect2, varscan2
- P3H1 | c.1831G>T p.D611Y | Missense Mutation (SNP) | VAF 84/189 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs200935208; called by muse, mutect2, varscan2
- PASD1 | c.1069C>G p.Q357E | Missense Mutation (SNP) | VAF 86/146 reads (59%) | SIFT tolerated (0.35); PolyPhen benign (0.224); catalogued as rs773014348; called by muse, mutect2, varscan2
- PCDH19 | c.644A>C p.D215A | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.998); catalogued as rs935781189; called by muse, mutect2
- PCDHB13 | c.1315G>A p.V439M | Missense Mutation (SNP) | VAF 159/275 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV53393831; called by muse, mutect2, varscan2
- PCDHGB1 | c.133G>T p.V45L | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs551145874, COSV53913385; called by muse, mutect2, varscan2
- PCNX2 | c.4249G>A p.D1417N | Missense Mutation (SNP) | VAF 74/515 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1237031185, COSV99265907; called by muse, mutect2, varscan2
- PER2 | c.196G>A p.G66R | Missense Mutation (SNP) | VAF 54/410 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs1432963906; called by muse, mutect2, varscan2
- PEX12 | c.605G>A p.R202Q | Missense Mutation (SNP) | VAF 41/368 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.821); catalogued as rs758225297; called by muse, mutect2, varscan2
- PGAP6 | c.1517G>T p.G506V | Missense Mutation (SNP) | VAF 43/195 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51739093; called by muse, mutect2, varscan2
- PGK2 | c.164C>A p.A55D | Missense Mutation (SNP) | VAF 100/278 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59165222; called by muse, mutect2, varscan2
- PHKB | c.2633G>A p.W878* | Nonsense Mutation (SNP) | VAF 52/388 reads (13%) | catalogued as rs1000274245, COSV100067489; called by muse, mutect2, varscan2
- PIN4 | c.353C>A p.P118Q (on ENST00000664196; = p.P93Q on NM_006223.4) | Missense Mutation (SNP) | VAF 86/179 reads (48%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.844); catalogued as rs1423088655, COSV54485019; called by muse, mutect2, varscan2
- PLCE1 | c.1141C>G p.P381A | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0); catalogued as rs754933489, COSV53357882; called by muse, mutect2, varscan2
- POTEA | c.104G>T p.C35F | Missense Mutation (SNP) | VAF 102/290 reads (35%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.731); catalogued as rs527259841; called by muse, mutect2, varscan2
- PPP1R21 | c.1412C>T p.S471L | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.658); catalogued as COSV54289978; called by muse, mutect2, varscan2
- PPP3CA | c.1429G>T p.D477Y | Missense Mutation (SNP) | VAF 59/94 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100548076, COSV59921233; called by muse, mutect2, varscan2
- PRAMEF17 | c.917C>A p.A306D | Missense Mutation (SNP) | VAF 26/153 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs1166640954; called by muse, varscan2
- PRDM10 | c.2926C>T p.Q976* | Nonsense Mutation (SNP) | VAF 12/142 reads (8%) | catalogued as COSV58802665; called by muse, mutect2
- PSG9 | c.665C>A p.P222Q | Missense Mutation (SNP) | VAF 206/209 reads (99%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as rs749016381; called by muse, mutect2, varscan2
- PSMD3 | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 171/301 reads (57%) | SIFT tolerated (0.24); PolyPhen benign (0.062); catalogued as rs555631976; called by muse, mutect2, varscan2
- PTPRD | c.3886G>T p.E1296* | Nonsense Mutation (SNP) | VAF 72/82 reads (88%) | catalogued as COSV61926583, COSV61978921; called by muse, mutect2, varscan2
- PXDNL | c.886A>T p.R296* | Nonsense Mutation (SNP) | VAF 77/418 reads (18%) | catalogued as COSV62487640; called by muse, mutect2, varscan2
- QTRT2 | c.904C>T p.Q302* | Nonsense Mutation (SNP) | VAF 13/24 reads (54%) | catalogued as rs764847068; called by muse, mutect2, varscan2
- RAB3IL1 | c.1006G>T p.A336S | Missense Mutation (SNP) | VAF 70/126 reads (56%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.505); catalogued as rs749370411; called by muse, mutect2, varscan2
- RASA2 | c.502A>G p.T168A | Missense Mutation (SNP) | VAF 41/155 reads (26%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs770448162; called by muse, mutect2, varscan2
- RBMXL2 | c.581C>T p.P194L | Missense Mutation (SNP) | VAF 60/108 reads (56%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs755396057; called by muse, mutect2, varscan2
- RGS7 | c.1231G>A p.V411M | Missense Mutation (SNP) | VAF 69/475 reads (15%) | SIFT tolerated (0.58); PolyPhen benign (0.279); catalogued as rs372505807; called by muse, mutect2, varscan2
- RNF115 | c.704A>T p.Y235F | Missense Mutation (SNP) | VAF 131/266 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0.069); catalogued as rs782790501; called by muse, mutect2, varscan2
- RPTN | c.1841G>T p.G614V | Missense Mutation (SNP) | VAF 294/631 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60169158; called by muse, mutect2, varscan2
- RRM1 | c.763A>G p.I255V | Missense Mutation (SNP) | VAF 18/147 reads (12%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.074); catalogued as rs779004662; called by muse, mutect2, varscan2
- RTN1 | c.442C>A p.P148T | Missense Mutation (SNP) | VAF 78/125 reads (62%) | SIFT tolerated (0.08); PolyPhen benign (0.276); catalogued as COSV50718699, COSV50719661; called by muse, mutect2, varscan2
- RYR2 | c.9460G>T p.A3154S | Missense Mutation (SNP) | VAF 64/191 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as COSV63677166; called by muse, mutect2, varscan2
- RYR3 | c.4541G>T p.R1514L | Missense Mutation (SNP) | VAF 50/107 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as COSV66776059; called by muse, mutect2, varscan2
- SCARA5 | c.728C>T p.T243M | Missense Mutation (SNP) | VAF 48/325 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.877); catalogued as rs765093547; called by muse, mutect2, varscan2
- SEMA3D | c.446G>T p.G149V | Missense Mutation (SNP) | VAF 28/48 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99033659; called by muse, mutect2, varscan2
- SEMA4A | c.1587del p.N530Tfs*2 | Frame Shift Del (DEL) | VAF 21/94 reads (22%) | catalogued as rs1558163897; called by mutect2, pindel
- SF3A1 | c.803G>C p.R268P | Missense Mutation (SNP) | VAF 91/342 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99305781; called by muse, mutect2, varscan2
- SKOR1 | c.2626C>T p.R876C | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs943427929, COSV58250085; called by muse, mutect2, varscan2
- SLC3A1 | c.1511G>A p.R504H | Missense Mutation (SNP) | VAF 41/214 reads (19%) | SIFT tolerated (0.57); PolyPhen benign (0.161); catalogued as rs753527558, COSV53224516; called by muse, mutect2, varscan2
- SLC4A3 | c.2731C>A p.R911S | Missense Mutation (SNP) | VAF 153/316 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56093013; called by muse, mutect2, varscan2
- SLC5A11 | c.991C>T p.R331C | Missense Mutation (SNP) | VAF 107/204 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs932697713, COSV61741032; called by muse, mutect2, varscan2
- SLC7A13 | c.863C>A p.A288E | Missense Mutation (SNP) | VAF 64/65 reads (98%) | SIFT tolerated (0.54); PolyPhen benign (0.045); catalogued as COSV52532273; called by muse, mutect2, varscan2
- SNTG1 | c.1310C>T p.S437F | Missense Mutation (SNP) | VAF 28/137 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99387058; called by muse, mutect2, varscan2
- SP3 | c.1334C>G p.P445R | Missense Mutation (SNP) | VAF 91/242 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100022002; called by muse, mutect2, varscan2
- SPATA31A6 | c.1024G>T p.E342* | Nonsense Mutation (SNP) | VAF 217/496 reads (44%) | catalogued as COSV60534229; called by muse, mutect2, varscan2
- SPTA1 | c.3189-1G>A p.X1063_splice | Splice Site (SNP) | VAF 129/418 reads (31%) | catalogued as COSV63760610; called by muse, mutect2, varscan2
- SRCAP | c.6724G>A p.E2242K | Missense Mutation (SNP) | VAF 37/155 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV52679522; called by muse, mutect2, varscan2
- SRCAP | c.6986G>A p.R2329Q | Missense Mutation (SNP) | VAF 28/196 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.715); catalogued as rs1386993634; called by muse, mutect2, varscan2
- STAB1 | c.7091C>A p.T2364K | Missense Mutation (SNP) | VAF 62/120 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.138); catalogued as COSV100195323; called by muse, mutect2, varscan2
- STXBP5L | c.397G>C p.D133H | Missense Mutation (SNP) | VAF 74/130 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV56510181, COSV56514530; called by muse, mutect2, varscan2
- SUGCT | c.1196G>T p.R399M (on ENST00000335693 / NM_001193313.2; = p.R425M on NM_024728.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 186/195 reads (95%) | SIFT tolerated (0.15); PolyPhen benign (0.019); catalogued as COSV100000648; called by muse, mutect2, varscan2
- SULF1 | c.217G>T p.G73W | Missense Mutation (SNP) | VAF 123/273 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs201774043, COSV52690552; called by muse, mutect2, varscan2
- SUN3 | c.688C>T p.L230F | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.277); catalogued as COSV99813977, COSV99814362; called by muse, mutect2, varscan2
- SVEP1 | c.1876del p.A626Qfs*25 | Frame Shift Del (DEL) | VAF 45/129 reads (35%) | catalogued as COSV57049750; called by mutect2, pindel, varscan2
- SYNE1 | c.16868G>A p.R5623H (on ENST00000367255 / NM_182961.4; = p.R5552H on NM_033071.3) | Missense Mutation (SNP) | VAF 64/184 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs753544584; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TAP1 | c.2005A>G p.M669V | Missense Mutation (SNP) | VAF 71/404 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.049); catalogued as rs765958228; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TBC1D14 | c.974C>G p.A325G | Missense Mutation (SNP) | VAF 28/160 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); catalogued as rs1367771456; called by muse, mutect2, varscan2
- TBCK | c.197G>T p.R66L | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs35784409; called by muse, mutect2, varscan2
- TBL3 | c.1909G>A p.E637K | Missense Mutation (SNP) | VAF 16/188 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.51); catalogued as rs200275880; called by muse, mutect2
- TENT5D | c.275C>A p.P92Q | Missense Mutation (SNP) | VAF 80/143 reads (56%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.952); catalogued as COSV57638237; called by muse, mutect2, varscan2
- TG | c.1589C>G p.S530C | Missense Mutation (SNP) | VAF 497/896 reads (55%) | SIFT tolerated (0.19); PolyPhen benign (0.319); catalogued as COSV55071873; called by muse, mutect2, varscan2
- TGFBI | c.1042G>T p.G348W | Missense Mutation (SNP) | VAF 33/228 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370797081; called by muse, mutect2, varscan2
- TLL2 | c.2630A>G p.Q877R | Missense Mutation (SNP) | VAF 82/216 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1287812731; called by muse, mutect2, varscan2
- TMEFF2 | c.592G>A p.D198N | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.17); PolyPhen probably damaging (1); catalogued as COSV55840180; called by muse, mutect2, varscan2
- TMEM200A | c.994C>T p.P332S | Missense Mutation (SNP) | VAF 63/144 reads (44%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs1331253259; called by muse, mutect2, varscan2
- TMEM260 | c.716C>T p.S239L | Missense Mutation (SNP) | VAF 53/447 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99839844; called by muse, mutect2, varscan2
- TNN | c.412C>T p.L138= | Splice Region (SNP) | VAF 32/204 reads (16%) | catalogued as COSV53420870; called by muse, mutect2, varscan2
- TPTE | c.1602G>T p.E534D (on ENST00000618007 / NM_199261.4; = p.E516D on NM_199259.4) | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.449); catalogued as rs1319960887; called by muse, mutect2, varscan2
- TRAJ53 | c.56C>A p.T19N | Missense Mutation (SNP) | VAF 48/119 reads (40%) | PolyPhen probably damaging (0.944); catalogued as rs900687390; called by muse, mutect2, varscan2
- TRAPPC9 | c.2580C>G p.F860L | Missense Mutation (SNP) | VAF 72/1052 reads (7%) | SIFT tolerated (0.44); PolyPhen benign (0.085); catalogued as COSV66896403; called by muse, mutect2
- TRIM10 | c.865C>A p.P289T | Missense Mutation (SNP) | VAF 140/213 reads (66%) | SIFT deleterious (0.04); PolyPhen benign (0.15); catalogued as COSV100939565; called by muse, mutect2, varscan2
- TRIM58 | c.1384A>G p.T462A | Missense Mutation (SNP) | VAF 62/172 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as rs1201819173; called by muse, mutect2, varscan2
- TRIM7 | c.176G>T p.R59L | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.4); PolyPhen benign (0.118); catalogued as rs954710762; called by muse, mutect2, varscan2
- TRPC5 | c.599A>G p.Y200C | Missense Mutation (SNP) | VAF 152/198 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53285039; called by muse, mutect2, varscan2
- UBR2 | c.1597G>T p.E533* | Nonsense Mutation (SNP) | VAF 78/137 reads (57%) | catalogued as COSV65749302; called by muse, mutect2, varscan2
- UNC13C | c.620G>T p.W207L | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0); catalogued as COSV52891998; called by muse, mutect2, varscan2
- USH2A | c.13561C>G p.P4521A | Missense Mutation (SNP) | VAF 42/124 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.558); catalogued as COSV56406267; called by muse, mutect2, varscan2
- USH2A | c.9226G>T p.D3076Y | Missense Mutation (SNP) | VAF 120/394 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV56401181, COSV56439100; called by muse, mutect2, varscan2
- USP30 | c.1388C>A p.A463D | Missense Mutation (SNP) | VAF 54/315 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as COSV57448828; called by muse, mutect2, varscan2
- USP6 | c.540C>A p.N180K | Missense Mutation (SNP) | VAF 312/384 reads (81%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.913); catalogued as rs750862063; called by muse, mutect2, varscan2
- VAT1L | c.367G>A p.G123R | Missense Mutation (SNP) | VAF 60/168 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758626119, COSV56817365; called by muse, mutect2
- VAV3 | c.1545C>A p.D515E | Missense Mutation (SNP) | VAF 35/72 reads (49%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV58377874; called by muse, mutect2, varscan2
- VMP1 | c.1193G>A p.R398Q | Missense Mutation (SNP) | VAF 43/245 reads (18%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as rs368929171; called by muse, mutect2, varscan2
- VRTN | c.1082C>T p.P361L | Missense Mutation (SNP) | VAF 30/252 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.011); catalogued as rs775926527, COSV56441332; called by muse, varscan2
- WDR97 | c.1459G>A p.E487K | Missense Mutation (SNP) | VAF 37/612 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1250878822; called by muse, mutect2
- WSCD2 | c.140G>A p.G47E | Missense Mutation (SNP) | VAF 103/196 reads (53%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs753595241; called by mutect2, varscan2
- XIRP2 | c.7027C>T p.L2343F (on ENST00000628543; = p.L2518F on NM_152381.6) | Missense Mutation (SNP) | VAF 29/236 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.422); catalogued as COSV54699812; called by muse, mutect2, varscan2
- XIRP2 | c.8725G>T p.V2909L (on ENST00000628543; = p.V3084L on NM_152381.6) | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.024); catalogued as COSV54728257, COSV99039766; called by muse, mutect2, varscan2
- ZEB2 | c.2156G>T p.S719I | Missense Mutation (SNP) | VAF 71/103 reads (69%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV100355670; called by muse, mutect2, varscan2
- ZFHX3 | c.6115C>T p.P2039S | Missense Mutation (SNP) | VAF 35/184 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.196); catalogued as rs760180670; called by muse, mutect2, varscan2
- ZFPM1 | c.1411G>A p.E471K | Missense Mutation (SNP) | VAF 40/203 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.045); catalogued as COSV60324082; called by muse, mutect2, varscan2
- ZNF232 | c.992A>G p.Y331C | Missense Mutation (SNP) | VAF 45/445 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.096); catalogued as rs745741402; called by muse, mutect2
- ZNF423 | c.2211C>G p.F737L (on ENST00000563137 / NM_001379286.1; = p.F729L on NM_015069.4) | Missense Mutation (SNP) | VAF 34/176 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99283511; called by muse, mutect2, varscan2
- ZNF438 | c.172C>T p.R58C | Missense Mutation (SNP) | VAF 72/259 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as rs199999473, COSV59194055; called by muse, mutect2, varscan2
- ZNF514 | c.205G>T p.G69* | Nonsense Mutation (SNP) | VAF 112/117 reads (96%) | catalogued as COSV99727697; called by muse, mutect2, varscan2
- ZNF529 | c.817C>G p.Q273E | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs765956981; called by muse, mutect2, varscan2
- ZNF705A | c.254A>T p.K85M | Missense Mutation (SNP) | VAF 99/210 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as rs1424881100; called by muse, mutect2, varscan2
- ZNF717 | c.751G>T p.V251F | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs76889571, COSV68858133; called by muse, mutect2, varscan2
- ZP4 | c.1012G>T p.V338L | Missense Mutation (SNP) | VAF 117/204 reads (57%) | SIFT tolerated (0.11); PolyPhen benign (0.253); catalogued as rs376995776; called by muse, mutect2, varscan2
- ZSCAN1 | c.707C>A p.S236* | Nonsense Mutation (SNP) | VAF 65/223 reads (29%) | catalogued as rs761346628, COSV56609383; called by muse, mutect2, varscan2
- AATK | c.2749T>A p.Y917N (on ENST00000326724 / NM_001080395.3; = p.Y814N on NM_004920.2) | Missense Mutation (SNP) | VAF 58/423 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- ABCC9 | c.1091T>G p.L364R | Missense Mutation (SNP) | VAF 98/205 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AC245033.1 | c.1677C>T p.D559= | Splice Region (SNP) | VAF 94/441 reads (21%) | called by muse, mutect2, varscan2
- ACIN1 | c.956_969del p.M319Tfs*25 | Frame Shift Del (DEL) | VAF 34/273 reads (12%) | called by mutect2, pindel
- ACOX1 | c.361G>C p.E121Q | Missense Mutation (SNP) | VAF 82/589 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ACSS2 | c.266G>A p.G89E | Missense Mutation (SNP) | VAF 35/355 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2
- ADAM23 | c.1912G>A p.G638R | Missense Mutation (SNP) | VAF 175/253 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAMTS1 | c.1609G>T p.G537W | Missense Mutation (SNP) | VAF 70/72 reads (97%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ADAMTS1 | c.1608A>C p.E536D | Missense Mutation (SNP) | VAF 69/72 reads (96%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAMTS16 | c.745T>C p.C249R | Missense Mutation (SNP) | VAF 76/221 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ADGRA3 | c.687G>T p.K229N | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- ADGRE1 | c.1960G>T p.A654S | Missense Mutation (SNP) | VAF 81/87 reads (93%) | SIFT tolerated (0.09); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- ALPK3 | c.4452C>G p.I1484M | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AMER1 | c.3128G>T p.S1043I | Missense Mutation (SNP) | VAF 58/91 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- AMY2B | c.482G>T p.G161V | Missense Mutation (SNP) | VAF 74/276 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ANK1 | c.3575C>A p.T1192N | Missense Mutation (SNP) | VAF 342/464 reads (74%) | SIFT deleterious (0); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- ANXA8 | c.296C>G p.A99G | Missense Mutation (SNP) | VAF 45/706 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2
- ARMC4 | c.2007C>G p.I669M | Missense Mutation (SNP) | VAF 75/200 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ARMT1 | c.1126G>T p.D376Y | Missense Mutation (SNP) | VAF 57/106 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ARRDC1 | c.79A>G p.T27A | Missense Mutation (SNP) | VAF 11/137 reads (8%) | SIFT tolerated (0.54); PolyPhen benign (0.003); called by muse, mutect2
- ART3 | c.733C>G p.Q245E | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.438); called by muse, mutect2, varscan2
- ATG2B | c.3360A>T p.K1120N | Missense Mutation (SNP) | VAF 29/216 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- ATP10B | c.2444T>A p.L815Q | Missense Mutation (SNP) | VAF 40/171 reads (23%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- ATP6V0A2 | c.1547A>T p.Q516L | Missense Mutation (SNP) | VAF 167/422 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- ATP6V1G3 | c.27C>A p.H9Q | Missense Mutation (SNP) | VAF 202/331 reads (61%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BRPF3 | c.1752G>T p.Q584H | Missense Mutation (SNP) | VAF 27/130 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- C10orf88 | c.161C>T p.P54L | Missense Mutation (SNP) | VAF 33/143 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- C12orf66 | c.836G>T p.R279L | Missense Mutation (SNP) | VAF 93/410 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- C17orf80 | c.1687G>A p.G563R | Missense Mutation (SNP) | VAF 29/220 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C1QTNF3 | c.241G>A p.G81R | Missense Mutation (SNP) | VAF 16/237 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- C6 | c.25T>A p.F9I | Missense Mutation (SNP) | VAF 50/611 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.023); called by muse, mutect2
- C6orf118 | c.937-1G>C p.X313_splice | Splice Site (SNP) | VAF 33/58 reads (57%) | called by muse, mutect2, varscan2
- CACNA1B | c.168G>T p.M56I | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- CACNA1D | c.1299G>T p.E433D | Missense Mutation (SNP) | VAF 47/138 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- CADM2 | c.613G>C p.V205L (on ENST00000407528 / NM_001167674.2; = p.V207L on NM_153184.4) | Missense Mutation (SNP) | VAF 39/133 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- CALD1 | c.184G>T p.V62L | Missense Mutation (SNP) | VAF 54/136 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- CCDC168 | c.7754G>T p.G2585V | Missense Mutation (SNP) | VAF 56/79 reads (71%) | SIFT tolerated (0.22); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- CCDC170 | c.1935G>C p.K645N | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- CCDC171 | c.3031C>A p.L1011I | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.36); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CCDC89 | c.349G>C p.E117Q | Missense Mutation (SNP) | VAF 43/332 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CCL3 | c.86C>A p.T29K | Missense Mutation (SNP) | VAF 104/345 reads (30%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- CCNB3 | c.2209G>T p.A737S | Missense Mutation (SNP) | VAF 103/200 reads (52%) | SIFT tolerated (0.24); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CCNYL1 | c.415A>G p.R139G (on ENST00000295414 / NM_001330218.2; = p.R69G on NM_152523.2) | Missense Mutation (SNP) | VAF 19/212 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.434); called by muse, mutect2
- CDH23 | c.8641G>T p.V2881F | Missense Mutation (SNP) | VAF 77/287 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- CDH5 | c.1895G>T p.G632V | Missense Mutation (SNP) | VAF 33/181 reads (18%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.524); called by muse, mutect2, varscan2
- CDHR1 | c.1117del p.Q373Rfs*42 | Frame Shift Del (DEL) | VAF 96/221 reads (43%) | called by mutect2, pindel, varscan2
- CENPJ | c.2769G>C p.E923D | Missense Mutation (SNP) | VAF 46/515 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- CEP135 | c.3292dup p.R1098Kfs*6 | Frame Shift Ins (INS) | VAF 28/127 reads (22%) | called by mutect2, pindel, varscan2
- CEP250 | c.4992G>T p.K1664N | Missense Mutation (SNP) | VAF 39/562 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.302); called by muse, mutect2
- CFAP47 | c.2128T>A p.S710T | Missense Mutation (SNP) | VAF 18/137 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- CFAP47 | c.6914G>T p.R2305L | Missense Mutation (SNP) | VAF 114/266 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CFAP94 | c.1164G>T p.L388F (on ENST00000320267 / NM_001352064.2; = p.L394F on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 90/173 reads (52%) | SIFT tolerated (0.18); PolyPhen benign (0.357); called by muse, mutect2, varscan2
- CHD6 | c.3322G>T p.G1108C | Missense Mutation (SNP) | VAF 106/243 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHD8 | c.1922C>T p.A641V (on ENST00000646647 / NM_001170629.2; = p.A362V on NM_020920.4) | Missense Mutation (SNP) | VAF 45/169 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- CHL1 | c.2569G>A p.D857N (on ENST00000397491 / NM_001253387.1; = p.D873N on NM_006614.4) | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- CLDN14 | c.680C>A p.S227* | Nonsense Mutation (SNP) | VAF 85/173 reads (49%) | called by muse, mutect2, varscan2
- CLEC1A | c.474G>A p.W158* | Nonsense Mutation (SNP) | VAF 19/130 reads (15%) | called by muse, mutect2, varscan2
- CLEC1A | c.56C>A p.T19N | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- CLEC3A | c.488G>A p.W163* (on ENST00000651443; = p.W154* on NM_005752.6) | Nonsense Mutation (SNP) | VAF 119/354 reads (34%) | called by muse, mutect2, varscan2
- CLMN | c.648G>T p.R216S | Missense Mutation (SNP) | VAF 64/95 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- CLSPN | c.1847G>T p.R616L | Missense Mutation (SNP) | VAF 49/195 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CNPY3 | c.8C>G p.S3* | Nonsense Mutation (SNP) | VAF 47/134 reads (35%) | called by muse, varscan2
- COL4A2 | c.1810G>T p.G604C | Missense Mutation (SNP) | VAF 111/168 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COP1 | c.652A>T p.R218W | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); called by muse, mutect2, varscan2
- CORIN | c.661G>C p.E221Q | Missense Mutation (SNP) | VAF 52/114 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- CPA3 | c.872G>C p.R291T | Missense Mutation (SNP) | VAF 56/367 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- CPAMD8 | c.1037G>A p.C346Y (on ENST00000651564; = p.C299Y on NM_015692.5) | Missense Mutation (SNP) | VAF 112/150 reads (75%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2
- CPNE8 | c.261dup p.E88* | Frame Shift Ins (INS) | VAF 26/58 reads (45%) | called by mutect2, pindel, varscan2
- CPOX | c.586G>C p.D196H | Missense Mutation (SNP) | VAF 34/220 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CRP | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 45/257 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- CSMD1 | c.9652C>A p.P3218T (on ENST00000520002; = p.P3217T on NM_033225.6) | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.426); called by muse, mutect2, varscan2
- CSMD1 | c.5796C>A p.Y1932* (on ENST00000520002; = p.Y1931* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 141/206 reads (68%) | called by muse, mutect2, varscan2
- CSMD2 | c.4903T>A p.Y1635N | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CTAGE9 | c.1310C>T p.A437V | Missense Mutation (SNP) | VAF 155/369 reads (42%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- CYP2R1 | c.1012A>T p.K338* | Nonsense Mutation (SNP) | VAF 19/82 reads (23%) | called by muse, mutect2, varscan2
- DACH1 | c.917del p.P306Rfs*12 | Frame Shift Del (DEL) | VAF 66/132 reads (50%) | called by mutect2, pindel, varscan2
- DECR1 | c.886G>T p.V296F | Missense Mutation (SNP) | VAF 14/177 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); called by muse, mutect2
- DHDDS | c.951G>C p.L317F (on ENST00000236342 / NM_001319959.1; = p.L318F on NM_024887.3) | Missense Mutation (SNP) | VAF 100/287 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- DIXDC1 | c.619G>A p.G207R | Missense Mutation (SNP) | VAF 44/331 reads (13%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DMD | c.9823G>C p.E3275Q | Missense Mutation (SNP) | VAF 25/175 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAH10 | c.7992T>A p.H2664Q (on ENST00000409039; = p.H2603Q on NM_207437.3) | Missense Mutation (SNP) | VAF 88/160 reads (55%) | SIFT tolerated (0.25); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DNAH14 | c.2520A>T p.E840D (on ENST00000445597; = p.E906D on NM_001367479.1) | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT tolerated (0.47); PolyPhen benign (0.049); called by muse, mutect2
- DNAH3 | c.5392G>A p.A1798T | Missense Mutation (SNP) | VAF 92/206 reads (45%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DNAH8 | c.6086G>A p.R2029K | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- DOCK10 | c.3126C>G p.Y1042* | Nonsense Mutation (SNP) | VAF 42/156 reads (27%) | called by muse, mutect2, varscan2
- DPEP1 | c.1000dup p.T334Nfs*11 | Frame Shift Ins (INS) | VAF 79/259 reads (31%) | called by mutect2, varscan2
- DPEP1 | c.1001delinsAA p.T334Kfs*11 | Frame Shift Ins (INS) | VAF 64/321 reads (20%) | called by mutect2*, pindel, varscan2*
- DSG2 | c.1185T>G p.I395M | Missense Mutation (SNP) | VAF 47/128 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- DYNC2H1 | c.10129C>G p.P3377A | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.574); called by muse, varscan2
- EEF1D | c.795G>T p.K265N | Missense Mutation (SNP) | VAF 68/259 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.609); called by muse, varscan2
- EIF2S2 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- EIF4E2 | c.220A>T p.S74C | Missense Mutation (SNP) | VAF 86/246 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- ERN1 | c.2669G>T p.R890M | Missense Mutation (SNP) | VAF 25/216 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ESX1 | c.564G>T p.Q188H | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- EYS | c.6328A>T p.N2110Y | Missense Mutation (SNP) | VAF 117/356 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- FAM169A | c.808C>G p.Q270E | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- FAM209B | c.91G>T p.E31* | Nonsense Mutation (SNP) | VAF 262/639 reads (41%) | called by muse, mutect2, varscan2
- FAM47A | c.744_747del p.P249Gfs*16 | Frame Shift Del (DEL) | VAF 121/293 reads (41%) | called by mutect2, pindel, varscan2
- FAM9A | c.682del p.E228Rfs*71 | Frame Shift Del (DEL) | VAF 102/438 reads (23%) | called by mutect2, pindel, varscan2
- FAP | c.2250C>A p.H750Q | Missense Mutation (SNP) | VAF 125/224 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- FASN | c.5992G>C p.G1998R | Missense Mutation (SNP) | VAF 437/774 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAT1 | c.6135G>T p.E2045D | Missense Mutation (SNP) | VAF 85/164 reads (52%) | SIFT tolerated (0.67); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- FAT2 | c.7383C>A p.F2461L | Missense Mutation (SNP) | VAF 38/129 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FAXC | c.473C>G p.S158C | Missense Mutation (SNP) | VAF 97/171 reads (57%) | SIFT tolerated (0.26); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- FER1L5 | c.2332_2334del p.V778del (on ENST00000623019; = p.V783del on NM_001293083.2) | In Frame Del (DEL) | VAF 26/135 reads (19%) | called by mutect2, pindel, varscan2
- FER1L6 | c.137G>A p.G46E | Missense Mutation (SNP) | VAF 138/590 reads (23%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- FER1L6 | c.5174C>A p.A1725D | Missense Mutation (SNP) | VAF 115/532 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FGF13 | c.496G>T p.G166C | Missense Mutation (SNP) | VAF 437/448 reads (98%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FMN2 | c.845G>T p.S282I | Missense Mutation (SNP) | VAF 43/114 reads (38%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- FOXC2 | c.1127C>G p.A376G | Missense Mutation (SNP) | VAF 52/113 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FREM3 | c.4876G>C p.D1626H | Missense Mutation (SNP) | VAF 27/254 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- FYB1 | c.89C>G p.S30* | Nonsense Mutation (SNP) | VAF 156/653 reads (24%) | called by muse, mutect2, varscan2
- GAK | c.569G>C p.C190S | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- GATA4 | c.68C>A p.P23H | Missense Mutation (SNP) | VAF 86/396 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- GFRA4 | c.473C>T p.A158V (on ENST00000319242 / NM_145762.3; = p.P132S on NM_022139.4) | Missense Mutation (SNP) | VAF 73/114 reads (64%) | SIFT tolerated (0.11); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- GK | c.212C>A p.T71K | Missense Mutation (SNP) | VAF 43/307 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- GK3P | c.104T>A p.L35Q | Missense Mutation (SNP) | VAF 51/230 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- GLMP | c.34G>A p.G12R | Missense Mutation (SNP) | VAF 60/399 reads (15%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- GMPR | c.475G>T p.V159L | Missense Mutation (SNP) | VAF 194/257 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- GOLGA5 | c.841C>G p.R281G | Missense Mutation (SNP) | VAF 56/608 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- GOLGA6C | c.955C>T p.Q319* | Nonsense Mutation (SNP) | VAF 24/596 reads (4%) | called by muse, mutect2
- GOLGA6L4 | c.639G>C p.E213D | Missense Mutation (SNP) | VAF 131/316 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- GPR50 | c.1800C>A p.Y600* | Nonsense Mutation (SNP) | VAF 40/41 reads (98%) | called by muse, mutect2, varscan2
- GYS2 | c.256G>A p.D86N | Missense Mutation (SNP) | VAF 116/234 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- HAP1 | c.289C>A p.P97T | Missense Mutation (SNP) | VAF 78/291 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- HCK | c.254C>A p.A85D | Missense Mutation (SNP) | VAF 93/244 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HCN1 | c.817A>T p.R273W | Missense Mutation (SNP) | VAF 23/178 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- HCN3 | c.2260C>G p.P754A | Missense Mutation (SNP) | VAF 31/215 reads (14%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- HHIPL2 | c.2133G>T p.R711S | Missense Mutation (SNP) | VAF 183/276 reads (66%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HIPK3 | c.2035A>T p.T679S | Missense Mutation (SNP) | VAF 61/64 reads (95%) | SIFT tolerated (0.13); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- HNF1B | c.1172C>T p.P391L | Missense Mutation (SNP) | VAF 56/320 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.658); called by muse, mutect2, varscan2
- HOXC13 | c.98G>A p.G33E | Missense Mutation (SNP) | VAF 25/270 reads (9%) | SIFT tolerated, low confidence (0.29); PolyPhen probably damaging (0.931); called by muse, mutect2
- HRNR | c.1672T>A p.Y558N | Missense Mutation (SNP) | VAF 111/947 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- HSF2 | c.66C>A p.H22Q | Missense Mutation (SNP) | VAF 123/444 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IBTK | c.2809A>T p.R937* | Nonsense Mutation (SNP) | VAF 12/123 reads (10%) | called by muse, mutect2, varscan2
- ICAM3 | c.1206T>G p.I402M | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.574); called by muse, mutect2, varscan2
- IFT140 | c.1042G>T p.V348L | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.311); called by muse, mutect2, varscan2
- IGF1R | c.1228G>A p.G410R | Missense Mutation (SNP) | VAF 183/401 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGHV3-16 | c.82G>A p.G28R | Missense Mutation (SNP) | VAF 73/289 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.529); called by muse, mutect2, varscan2
- IGKV1-17 | c.29T>A p.L10Q | Missense Mutation (SNP) | VAF 228/348 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- IGLV3-19 | c.293C>G p.A98G | Missense Mutation (SNP) | VAF 62/170 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.084); called by muse, varscan2
- IGSF3 | c.1629G>A p.M543I (on ENST00000369486 / NM_001007237.3; = p.M563I on NM_001542.4) | Missense Mutation (SNP) | VAF 60/91 reads (66%) | SIFT deleterious (0.02); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ILF2 | c.446A>T p.Q149L | Missense Mutation (SNP) | VAF 13/231 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.015); called by muse, mutect2
- INAVA | c.1546T>A p.Y516N | Missense Mutation (SNP) | VAF 30/200 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- INSC | c.764C>A p.T255K | Missense Mutation (SNP) | VAF 92/106 reads (87%) | SIFT deleterious (0.02); PolyPhen benign (0.01); called by muse, mutect2
- INTS2 | c.119C>A p.P40Q | Missense Mutation (SNP) | VAF 8/180 reads (4%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.996); called by muse, mutect2
- IQCB1 | c.541G>A p.G181R | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.559); called by muse, mutect2, varscan2
- IQSEC2 | c.3763G>A p.G1255R | Missense Mutation (SNP) | VAF 33/240 reads (14%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.01); called by muse, varscan2
- ITGB1 | c.1432C>A p.H478N | Missense Mutation (SNP) | VAF 15/217 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.164); called by muse, mutect2
- ITSN2 | c.3178G>C p.V1060L | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- JMJD1C | c.1744G>T p.A582S | Missense Mutation (SNP) | VAF 108/199 reads (54%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- KAT6A | c.44A>G p.E15G | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- KAT6B | c.4303G>T p.E1435* | Nonsense Mutation (SNP) | VAF 130/386 reads (34%) | called by muse, mutect2, varscan2
- KCND1 | c.1366G>C p.E456Q | Missense Mutation (SNP) | VAF 29/204 reads (14%) | SIFT tolerated, low confidence (0.28); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- KCND2 | c.414G>T p.K138N | Missense Mutation (SNP) | VAF 151/241 reads (63%) | SIFT tolerated (0.1); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- KCNH7 | c.599T>C p.F200S | Missense Mutation (SNP) | VAF 108/311 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- KCNJ15 | c.217A>G p.T73A | Missense Mutation (SNP) | VAF 99/228 reads (43%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCNQ2 | c.929G>A p.G310D | Missense Mutation (SNP) | VAF 60/634 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KLHL29 | c.611A>G p.Y204C | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- KLRC2 | c.283C>A p.P95T | Missense Mutation (SNP) | VAF 58/214 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.167); called by mutect2, varscan2
- KRTAP16-1 | c.549_550del p.V185Afs*20 | Frame Shift Del (DEL) | VAF 32/280 reads (11%) | called by pindel, varscan2
- LCE1A | c.329G>T p.C110F | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- LCOR | c.379A>T p.K127* | Nonsense Mutation (SNP) | VAF 27/56 reads (48%) | called by muse, mutect2, varscan2
- LMLN | c.404del p.R135Hfs*111 | Frame Shift Del (DEL) | VAF 94/202 reads (47%) | called by mutect2, pindel, varscan2
- LMNB1 | c.1407G>A p.W469* | Nonsense Mutation (SNP) | VAF 25/108 reads (23%) | called by muse, mutect2, varscan2
- LMOD1 | c.638A>T p.E213V | Missense Mutation (SNP) | VAF 46/306 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- LPAR5 | c.974C>A p.T325K | Missense Mutation (SNP) | VAF 90/198 reads (45%) | SIFT tolerated (0.93); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- LRBA | c.2068G>C p.D690H | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRRC49 | c.1792G>A p.G598R | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- LRRC70 | c.35G>T p.R12L | Missense Mutation (SNP) | VAF 84/107 reads (79%) | SIFT tolerated (0.64); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- LRRK2 | c.1454C>T p.P485L | Missense Mutation (SNP) | VAF 71/522 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- LTBP2 | c.4228C>A p.R1410S | Missense Mutation (SNP) | VAF 442/733 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.469); called by muse, mutect2, varscan2
- MAFB | c.728G>T p.R243L | Missense Mutation (SNP) | VAF 328/649 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAGEB6B | c.308C>A p.S103Y | Missense Mutation (SNP) | VAF 185/385 reads (48%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.552); called by muse, mutect2, varscan2
- MAGEB6B | c.1036C>T p.Q346* | Nonsense Mutation (SNP) | VAF 91/317 reads (29%) | called by muse, mutect2, varscan2
- MALRD1 | c.3148T>G p.C1050G | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MAP3K6 | c.2542C>T p.P848S | Missense Mutation (SNP) | VAF 56/153 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MARCO | c.1556G>T p.S519I | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- MCAT | c.512-2A>T p.X171_splice | Splice Site (SNP) | VAF 37/88 reads (42%) | called by muse, mutect2, varscan2
- MEF2C | c.237del p.T80Qfs*9 | Frame Shift Del (DEL) | VAF 68/135 reads (50%) | called by mutect2, pindel, varscan2
- MEIS1 | c.175A>T p.M59L | Missense Mutation (SNP) | VAF 118/127 reads (93%) | SIFT tolerated (0.76); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- MINDY4B | c.824+1G>T p.X275_splice | Splice Site (SNP) | VAF 87/133 reads (65%) | called by muse, mutect2, varscan2
- MLEC | c.82G>T p.G28* | Nonsense Mutation (SNP) | VAF 18/110 reads (16%) | called by muse, mutect2, varscan2
- MORC1 | c.2284C>A p.L762I | Missense Mutation (SNP) | VAF 65/150 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- MPPED2 | c.760C>A p.H254N | Missense Mutation (SNP) | VAF 40/149 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- MRC2 | c.1569+1G>T p.X523_splice | Splice Site (SNP) | VAF 76/101 reads (75%) | called by muse, mutect2, varscan2
- MRM1 | c.170C>G p.P57R | Missense Mutation (SNP) | VAF 34/186 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MSLNL | c.1225C>A p.L409M | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- MSMB | c.207T>A p.C69* | Nonsense Mutation (SNP) | VAF 96/207 reads (46%) | called by muse, mutect2, varscan2
- MTOR | c.4002G>T p.Q1334H | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- MTUS2 | c.2308C>G p.L770V | Missense Mutation (SNP) | VAF 228/327 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MUC22 | c.668C>G p.S223C | Missense Mutation (SNP) | VAF 25/189 reads (13%) | SIFT deleterious, low confidence (0.05); called by muse, mutect2
- MUC4 | c.6079A>G p.T2027A | Missense Mutation (SNP) | VAF 129/554 reads (23%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.224); called by mutect2, varscan2
- MUC5B | c.6518G>A p.S2173N | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- MXRA5 | c.2559C>A p.H853Q | Missense Mutation (SNP) | VAF 104/315 reads (33%) | SIFT tolerated (0.94); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYH2 | c.4187A>C p.K1396T | Missense Mutation (SNP) | VAF 85/835 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYO18B | c.1513-3C>G | Splice Region (SNP) | VAF 37/304 reads (12%) | called by muse, mutect2, varscan2
- MYO7B | c.642del p.K215Sfs*12 | Frame Shift Del (DEL) | VAF 126/298 reads (42%) | called by mutect2, pindel, varscan2
- MYRF | c.1700C>T p.P567L (on ENST00000278836 / NM_001127392.3; = p.P558L on NM_013279.4) | Missense Mutation (SNP) | VAF 143/389 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- NEBL | c.446A>T p.K149I | Missense Mutation (SNP) | VAF 135/505 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.183); called by muse, mutect2, varscan2
- NECAB3 | c.139A>T p.R47* | Nonsense Mutation (SNP) | VAF 14/499 reads (3%) | called by muse, mutect2
- NLN | c.664G>T p.A222S | Missense Mutation (SNP) | VAF 25/38 reads (66%) | SIFT deleterious (0); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NLRP3 | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 78/649 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- NRAS | c.362C>T p.P121L | Missense Mutation (SNP) | VAF 86/321 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- NRN1 | c.56C>A p.A19E | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); called by muse, mutect2
- NTF4 | c.355G>T p.E119* | Nonsense Mutation (SNP) | VAF 28/135 reads (21%) | called by muse, varscan2
- NUP153 | c.4367C>G p.S1456C | Missense Mutation (SNP) | VAF 23/245 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NUP153 | c.803G>A p.G268E | Missense Mutation (SNP) | VAF 37/276 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NUP155 | c.723+2T>G p.X241_splice (on ENST00000231498 / NM_153485.3; = p.X182_splice on NM_004298.4) | Splice Site (SNP) | VAF 43/439 reads (10%) | called by muse, mutect2, varscan2
- NXPE3 | c.31T>C p.F11L | Missense Mutation (SNP) | VAF 89/237 reads (38%) | SIFT tolerated (0.97); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OGDHL | c.1422C>G p.C474W | Missense Mutation (SNP) | VAF 112/238 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR11H1 | c.338del p.T113Nfs*7 | Frame Shift Del (DEL) | VAF 12/43 reads (28%) | called by mutect2, varscan2
- OR13F1 | c.160C>A p.H54N | Missense Mutation (SNP) | VAF 61/117 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- OR2AT4 | c.343T>C p.S115P | Missense Mutation (SNP) | VAF 44/303 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- OR3A2 | c.227C>A p.S76* | Nonsense Mutation (SNP) | VAF 147/238 reads (62%) | called by muse, mutect2, varscan2
- OR4C11 | c.748G>C p.G250R | Missense Mutation (SNP) | VAF 74/157 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- OR4K1 | c.896G>T p.W299L | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR5L2 | c.315C>A p.C105* | Nonsense Mutation (SNP) | VAF 139/153 reads (91%) | called by muse, mutect2, varscan2
- OR6B2 | c.384C>A p.H128Q | Missense Mutation (SNP) | VAF 68/211 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.007); called by muse, mutect2
- OR6K6 | c.140A>T p.H47L (on ENST00000368144; = p.H23L on NM_001005184.1) | Missense Mutation (SNP) | VAF 148/332 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OSBPL8 | c.983C>T p.S328F | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- OTOGL | c.6337G>T p.D2113Y (on ENST00000547103; = p.D2104Y on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- OTUD7A | c.1365G>C p.E455D (on ENST00000307050 / NM_001382637.1; = p.E448D on NM_130901.3) | Missense Mutation (SNP) | VAF 40/85 reads (47%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PABPC5 | c.308C>A p.S103Y | Missense Mutation (SNP) | VAF 15/157 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- PALLD | c.556G>C p.A186P | Missense Mutation (SNP) | VAF 194/451 reads (43%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- PARD3 | c.26G>T p.R9L | Missense Mutation (SNP) | VAF 49/223 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- PCDHA12 | c.2308A>T p.M770L | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- PCDHGA9 | c.299C>A p.P100Q | Missense Mutation (SNP) | VAF 52/171 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- PCDHGB6 | c.548G>C p.R183T | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- PCMTD2 | c.691A>T p.R231* | Nonsense Mutation (SNP) | VAF 24/262 reads (9%) | called by muse, mutect2
- PCSK6 | c.1744G>T p.G582W | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PDE7B | c.492_494del p.E164del | In Frame Del (DEL) | VAF 23/123 reads (19%) | called by pindel, varscan2
- PDE9A | c.707C>A p.P236H | Missense Mutation (SNP) | VAF 59/164 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- PGAP6 | c.1516G>T p.G506C | Missense Mutation (SNP) | VAF 43/197 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PHKA2 | c.1270del p.D424Ifs*3 | Frame Shift Del (DEL) | VAF 76/404 reads (19%) | called by mutect2, pindel, varscan2
- PIGA | c.1024G>A p.E342K | Missense Mutation (SNP) | VAF 25/219 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- PIM2 | c.302G>T p.R101L | Missense Mutation (SNP) | VAF 24/326 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2
- PKD1 | c.7042A>G p.K2348E | Missense Mutation (SNP) | VAF 183/310 reads (59%) | SIFT tolerated (0.44); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- PKD1 | c.708G>T p.Q236H | Missense Mutation (SNP) | VAF 68/124 reads (55%) | SIFT tolerated (0.71); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- PLBD2 | c.860-1G>T p.X287_splice | Splice Site (SNP) | VAF 77/147 reads (52%) | called by muse, mutect2, varscan2
- PLBD2 | c.860G>T p.G287V | Missense Mutation (SNP) | VAF 79/149 reads (53%) | SIFT tolerated (0.26); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- PLCB1 | c.3440A>T p.E1147V | Missense Mutation (SNP) | VAF 38/124 reads (31%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- PLEKHG4B | c.2261G>T p.G754V (on ENST00000283426; = p.G1110V on NM_052909.5) | Missense Mutation (SNP) | VAF 200/588 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PLEKHG4B | c.2909C>T p.A970V (on ENST00000283426; = p.A1326V on NM_052909.5) | Missense Mutation (SNP) | VAF 69/577 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PLG | c.2383C>T p.R795C | Missense Mutation (SNP) | VAF 126/311 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLOD3 | c.2180G>T p.G727V | Missense Mutation (SNP) | VAF 336/531 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLRG1 | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 29/150 reads (19%) | SIFT tolerated (0.88); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- PLXNA1 | c.1027C>G p.Q343E | Missense Mutation (SNP) | VAF 12/280 reads (4%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.981); called by muse, mutect2
- POF1B | c.1177G>C p.D393H | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- POM121L12 | c.45dup p.W16Lfs*130 | Frame Shift Ins (INS) | VAF 35/90 reads (39%) | called by mutect2, pindel, varscan2
- PORCN | c.224T>C p.V75A | Missense Mutation (SNP) | VAF 82/528 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- POTEA | c.917A>G p.K306R (on ENST00000519951 / NM_001005365.2; = p.K260R on NM_001002920.1) | Missense Mutation (SNP) | VAF 69/144 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- POU3F3 | c.879C>A p.H293Q | Missense Mutation (SNP) | VAF 93/128 reads (73%) | SIFT tolerated (0.34); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PPM1G | c.870G>C p.E290D | Missense Mutation (SNP) | VAF 34/187 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.097); called by muse, varscan2
- PRB1 | c.434G>A p.G145E | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- PRKAA2 | c.1478C>G p.A493G | Missense Mutation (SNP) | VAF 53/186 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRKCB | c.169A>T p.I57F | Missense Mutation (SNP) | VAF 120/383 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- PRPF39 | c.1993C>T p.P665S | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.258); called by muse, mutect2
- PTCH2 | c.3134G>A p.G1045D | Missense Mutation (SNP) | VAF 137/356 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTK2B | c.1917G>C p.E639D | Missense Mutation (SNP) | VAF 184/519 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- PTTG1 | c.520T>A p.W174R | Missense Mutation (SNP) | VAF 48/139 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- QKI | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- QRICH1 | c.330G>T p.Q110H | Missense Mutation (SNP) | VAF 44/165 reads (27%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- RAD51AP2 | c.71A>T p.E24V | Missense Mutation (SNP) | VAF 87/186 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- RASGRP4 | c.1708C>A p.R570S | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RASIP1 | c.812C>A p.A271E | Missense Mutation (SNP) | VAF 43/45 reads (96%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RBM15 | c.409G>T p.G137W | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.825); called by mutect2, varscan2
- RBM15 | c.410G>T p.G137V | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.218); called by mutect2, varscan2
- RBM15B | c.832del p.R278Vfs*50 | Frame Shift Del (DEL) | VAF 68/225 reads (30%) | called by mutect2, pindel, varscan2
- RBMXL3 | c.1741C>A p.Q581K | Missense Mutation (SNP) | VAF 23/206 reads (11%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- RFX7 | c.635G>C p.R212P (on ENST00000559447 / NM_001368074.1; = p.R309P on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 136/269 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- RGS5 | c.500T>A p.L167Q | Missense Mutation (SNP) | VAF 19/154 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- RNF148 | c.576G>T p.M192I | Missense Mutation (SNP) | VAF 112/368 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RPS6KA6 | c.1966G>A p.A656T | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- RSRC2 | c.184A>G p.R62G | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- RTN2 | c.230G>A p.G77D | Missense Mutation (SNP) | VAF 47/327 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- RYR3 | c.6381C>A p.A2127= | Splice Region (SNP) | VAF 25/47 reads (53%) | called by muse, mutect2, varscan2
- SALL3 | c.719C>T p.P240L | Missense Mutation (SNP) | VAF 68/212 reads (32%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- SAP130 | c.2988+1G>T p.X996_splice | Splice Site (SNP) | VAF 78/132 reads (59%) | called by muse, mutect2, varscan2
- SAXO1 | c.749A>T p.E250V | Missense Mutation (SNP) | VAF 196/201 reads (98%) | SIFT deleterious (0); PolyPhen benign (0.406); called by muse, mutect2, varscan2
- SCG2 | c.628G>C p.G210R | Missense Mutation (SNP) | VAF 136/370 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- SCN3A | c.4807+5G>C | Splice Region (SNP) | VAF 20/177 reads (11%) | called by muse, mutect2, varscan2
- SCRT1 | c.32A>G p.K11R | Missense Mutation (SNP) | VAF 155/346 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- SCUBE1 | c.2669T>C p.I890T | Missense Mutation (SNP) | VAF 40/359 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SEL1L3 | c.2670-1G>T p.X890_splice | Splice Site (SNP) | VAF 22/61 reads (36%) | called by muse, mutect2, varscan2
- SEMA3B | c.401G>A p.G134E | Missense Mutation (SNP) | VAF 63/192 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SETD4 | c.620G>A p.R207K | Missense Mutation (SNP) | VAF 90/373 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SETX | c.7367G>C p.R2456T | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- SIPA1L2 | c.1996A>G p.T666A | Missense Mutation (SNP) | VAF 63/206 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- SIX4 | c.1835T>C p.V612A | Missense Mutation (SNP) | VAF 13/273 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.193); called by muse, mutect2
- SLC2A12 | c.785A>G p.Q262R | Missense Mutation (SNP) | VAF 77/157 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- SLC2A13 | c.1557_1559del p.F520del | In Frame Del (DEL) | VAF 48/176 reads (27%) | called by pindel, varscan2
- SLC8A1 | c.1268G>A p.G423D | Missense Mutation (SNP) | VAF 35/50 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLCO5A1 | c.230A>T p.N77I | Missense Mutation (SNP) | VAF 31/166 reads (19%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SMG5 | c.1021G>C p.E341Q | Missense Mutation (SNP) | VAF 51/460 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- SMYD5 | c.53G>T p.R18L | Missense Mutation (SNP) | VAF 168/174 reads (97%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- SNAPC1 | c.1063A>T p.S355C | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.439); called by muse, mutect2
- SOD3 | c.417C>A p.H139Q | Missense Mutation (SNP) | VAF 259/420 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SOS1 | c.2624T>G p.V875G | Missense Mutation (SNP) | VAF 10/267 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.435); called by muse, mutect2
- SPATA31E1 | c.1002C>A p.H334Q | Missense Mutation (SNP) | VAF 57/113 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- SRGAP1 | c.799G>C p.D267H | Missense Mutation (SNP) | VAF 100/132 reads (76%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- STAB1 | c.1153C>G p.Q385E | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- STYXL2 | c.1905G>T p.Q635H | Missense Mutation (SNP) | VAF 34/65 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- SUCNR1 | c.230C>T p.P77L | Missense Mutation (SNP) | VAF 58/133 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SUGP1 | c.194del p.P65Hfs*30 | Frame Shift Del (DEL) | VAF 133/185 reads (72%) | called by mutect2, pindel, varscan2
- SVEP1 | c.5924C>G p.T1975R | Missense Mutation (SNP) | VAF 62/143 reads (43%) | SIFT tolerated (0.48); PolyPhen benign (0.279); called by muse, mutect2, varscan2
- SYNE2 | c.2623G>T p.G875C | Missense Mutation (SNP) | VAF 236/390 reads (61%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.68); called by muse, mutect2, varscan2
- TAF15 | c.376C>T p.Q126* (on ENST00000605844 / NM_139215.3; = p.Q123* on NM_003487.4) | Nonsense Mutation (SNP) | VAF 53/263 reads (20%) | called by muse, mutect2, varscan2
- TCP10L | c.88A>G p.K30E | Missense Mutation (SNP) | VAF 64/74 reads (86%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- TDRD15 | c.4418C>A p.S1473* | Nonsense Mutation (SNP) | VAF 39/107 reads (36%) | called by muse, mutect2, varscan2
- TESPA1 | c.190T>C p.W64R | Missense Mutation (SNP) | VAF 186/279 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TEX38 | c.359C>A p.P120H | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- TFAP4 | c.298G>T p.E100* | Nonsense Mutation (SNP) | VAF 110/389 reads (28%) | called by muse, mutect2, varscan2
- TFDP3 | c.77C>T p.P26L | Missense Mutation (SNP) | VAF 45/46 reads (98%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- THSD7B | c.4192G>T p.G1398C (on ENST00000272643; = p.G1396C on NM_001316349.2) | Missense Mutation (SNP) | VAF 94/174 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TIGD2 | c.202C>G p.R68G | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- TLR6 | c.1665G>T p.W555C | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TLR8 | c.1473C>G p.N491K (on ENST00000218032 / NM_138636.5; = p.N509K on NM_016610.4) | Missense Mutation (SNP) | VAF 60/163 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TMEM121 | c.253G>C p.V85L | Missense Mutation (SNP) | VAF 47/239 reads (20%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- TMEM237 | c.1172C>A p.S391Y (on ENST00000409883 / NM_001044385.3; = p.S383Y on NM_152388.4) | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- TMEM263 | c.169G>T p.V57L | Missense Mutation (SNP) | VAF 93/189 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- TMEM40 | c.418_424+17del p.X140_splice | Splice Site (DEL) | VAF 10/30 reads (33%) | called by mutect2, pindel, varscan2
- TMOD1 | c.83G>A p.R28K | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TOP2B | c.4468A>G p.K1490E (on ENST00000264331 / NM_001330700.2; = p.K1485E on NM_001068.3) | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- TRHDE | c.2734G>T p.E912* | Nonsense Mutation (SNP) | VAF 86/394 reads (22%) | called by muse, mutect2, varscan2
- TRIM58 | c.340C>A p.L114M | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- TRPC4 | c.2700_2701insA p.G901Rfs*4 (on ENST00000379705 / NM_016179.4; = p.G906Rfs*4 on NM_003306.3) | Frame Shift Ins (INS) | VAF 24/114 reads (21%) | called by mutect2, pindel, varscan2
- TRPM6 | c.1661A>T p.N554I | Missense Mutation (SNP) | VAF 91/386 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TRPS1 | c.1127A>T p.E376V (on ENST00000220888 / NM_001330599.2; = p.E389V on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 104/491 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- TRPS1 | c.1126G>T p.E376* (on ENST00000220888 / NM_001330599.2; = p.E389* on NM_014112.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 106/499 reads (21%) | called by muse, mutect2, varscan2
- TSC2 | c.2286G>T p.L762F | Missense Mutation (SNP) | VAF 136/227 reads (60%) | SIFT tolerated (0.85); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TSPYL2 | c.523G>T p.E175* | Nonsense Mutation (SNP) | VAF 79/440 reads (18%) | called by muse, mutect2, varscan2
- TTC6 | c.2917G>T p.D973Y | Missense Mutation (SNP) | VAF 29/53 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TTLL13P | c.2318C>G p.S773* | Nonsense Mutation (SNP) | VAF 89/336 reads (26%) | called by muse, mutect2, varscan2
- UBR3 | c.5576A>T p.K1859M | Missense Mutation (SNP) | VAF 51/83 reads (61%) | SIFT tolerated (0.11); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- UNC13C | c.621G>T p.W207C | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- UNC45B | c.2605C>A p.L869M | Missense Mutation (SNP) | VAF 100/374 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- UNC5D | c.2474T>C p.L825P | Missense Mutation (SNP) | VAF 68/84 reads (81%) | SIFT tolerated (0.17); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- UNC79 | c.4549C>A p.H1517N (on ENST00000393151 / NM_001346218.2; = p.H1340N on NM_020818.5) | Missense Mutation (SNP) | VAF 99/183 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- UNC80 | c.8716A>T p.K2906* | Nonsense Mutation (SNP) | VAF 35/163 reads (21%) | called by muse, mutect2, varscan2
- USP48 | c.1451-3C>G | Splice Region (SNP) | VAF 58/206 reads (28%) | called by muse, mutect2, varscan2
- UTP18 | c.450G>T p.E150D | Missense Mutation (SNP) | VAF 77/116 reads (66%) | SIFT tolerated (0.13); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- VPS13B | c.3984G>C p.W1328C | Missense Mutation (SNP) | VAF 131/442 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.413); called by muse, mutect2, varscan2
- VWA5B1 | c.2223C>G p.C741W | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- WDFY4 | c.4052C>A p.A1351D | Missense Mutation (SNP) | VAF 117/230 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- WDR43 | c.1049T>C p.V350A | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT tolerated (0.84); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- WEE2 | c.243G>C p.L81F | Missense Mutation (SNP) | VAF 65/235 reads (28%) | SIFT tolerated (0.4); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- WIPF3 | c.472G>T p.A158S | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- XAGE5 | c.115del p.E39Kfs*89 | Frame Shift Del (DEL) | VAF 85/187 reads (45%) | called by mutect2, pindel, varscan2
- XIRP2 | c.2256T>A p.D752E (on ENST00000628543; = p.D927E on NM_152381.6) | Missense Mutation (SNP) | VAF 45/127 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- XKR6 | c.1846G>A p.V616I | Missense Mutation (SNP) | VAF 63/114 reads (55%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- YIPF6 | c.594C>A p.A198= | Splice Region (SNP) | VAF 72/119 reads (61%) | called by muse, mutect2, varscan2
- ZAN | c.6200G>T p.G2067V | Missense Mutation (SNP) | VAF 123/180 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZBTB2 | c.335G>T p.S112I | Missense Mutation (SNP) | VAF 162/291 reads (56%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- ZBTB21 | c.781C>T p.Q261* | Nonsense Mutation (SNP) | VAF 43/85 reads (51%) | called by muse, mutect2, varscan2
- ZC3H15 | c.93G>C p.L31F | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZFP82 | c.24C>A p.F8L | Missense Mutation (SNP) | VAF 107/109 reads (98%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- ZIC5 | c.1349T>C p.V450A | Missense Mutation (SNP) | VAF 234/354 reads (66%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- ZNF257 | c.3+1G>T p.X1_splice | Splice Site (SNP) | VAF 123/126 reads (98%) | called by muse, mutect2, varscan2
- ZNF441 | c.1510A>T p.K504* | Nonsense Mutation (SNP) | VAF 96/98 reads (98%) | called by muse, mutect2, varscan2
- ZNF521 | c.1837G>C p.E613Q | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- ZNF600 | c.503del p.G168Afs*10 | Frame Shift Del (DEL) | VAF 31/76 reads (41%) | called by mutect2, pindel, varscan2
- ZNF623 | c.1408C>G p.Q470E | Missense Mutation (SNP) | VAF 36/620 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.719); called by muse, mutect2
- ZNF626 | c.102A>T p.L34F | Missense Mutation (SNP) | VAF 259/267 reads (97%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- ZNF638 | c.8G>C p.R3P | Missense Mutation (SNP) | VAF 51/145 reads (35%) | PolyPhen benign (0.32); called by muse, mutect2, varscan2
- ZNF679 | c.799C>A p.P267T | Missense Mutation (SNP) | VAF 40/41 reads (98%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- ZNF699 | c.1928A>C p.*643Sext*2 | Nonstop Mutation (SNP) | VAF 8/27 reads (30%) | called by muse, varscan2
- ZNF804A | c.3503A>T p.Q1168L | Missense Mutation (SNP) | VAF 119/335 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- ZNF831 | c.4529G>T p.S1510I | Missense Mutation (SNP) | VAF 235/425 reads (55%) | SIFT tolerated (0.1); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- ZNF839 | c.824C>A p.S275* (on ENST00000558850 / NM_001267827.1; = p.S391* on NM_018335.5) | Nonsense Mutation (SNP) | VAF 19/84 reads (23%) | called by mutect2, varscan2
- ZNF853 | c.781C>A p.Q261K | Missense Mutation (SNP) | VAF 150/161 reads (93%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ZSCAN18 | c.1504C>G p.P502A | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACSM2A | c.1212C>A p.P404= (on ENST00000219054; = p.P325= on NM_001308169.2) | Silent (SNP) | VAF 34/92 reads (37%) | catalogued as COSV54584720; called by muse, mutect2, varscan2
- ADAM23 | c.2337C>A p.P779= | Silent (SNP) | VAF 58/388 reads (15%) | catalogued as rs571615571, COSV52217714; called by muse, varscan2
- ADCY1 | c.2658C>A p.G886= | Silent (SNP) | VAF 9/55 reads (16%) | called by muse, mutect2, varscan2
- AGBL1 | c.76C>T p.L26= | Silent (SNP) | VAF 23/128 reads (18%) | called by muse, varscan2
- AMER3 | c.1548C>A p.P516= | Silent (SNP) | VAF 28/50 reads (56%) | catalogued as rs1319690380; called by muse, mutect2, varscan2
- ANKRD13B | c.228G>A p.R76= | Silent (SNP) | VAF 27/173 reads (16%) | called by muse, mutect2, varscan2
- ARAP3 | c.213G>T p.L71= | Silent (SNP) | VAF 66/120 reads (55%) | called by muse, mutect2, varscan2
- ASB16 | c.1356C>A p.I452= | Silent (SNP) | VAF 105/150 reads (70%) | called by muse, mutect2, varscan2
- ATAD3B | c.429C>T p.A143= (on ENST00000308647; = p.A249= on NM_031921.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 53/55 reads (96%) | called by muse, mutect2, varscan2
- AXDND1 | c.825G>T p.V275= | Silent (SNP) | VAF 310/488 reads (64%) | called by muse, mutect2, varscan2
- BCR | c.570G>A p.K190= | Silent (SNP) | VAF 46/170 reads (27%) | called by muse, mutect2, varscan2
- BRINP1 | c.1878T>A p.P626= | Silent (SNP) | VAF 28/103 reads (27%) | catalogued as COSV99776462, COSV99777042; called by muse, mutect2, varscan2
- BTF3 | c.612G>A p.E204= (on ENST00000380591 / NM_001037637.1; = p.E160= on NM_001207.4) | Silent (SNP) | VAF 13/68 reads (19%) | catalogued as rs961437822; called by muse, mutect2, varscan2
- BUB3 | c.114C>G p.S38= | Silent (SNP) | VAF 43/195 reads (22%) | called by muse, mutect2, varscan2
- C1QL2 | c.447G>A p.A149= | Silent (SNP) | VAF 96/270 reads (36%) | called by muse, mutect2, varscan2
- CABS1 | c.853C>T p.L285= | Silent (SNP) | VAF 34/130 reads (26%) | catalogued as rs201758701; called by muse, mutect2, varscan2
- CAGE1 | c.2097G>A p.E699= (on ENST00000512086; = p.E563= on NM_205864.3) | Silent (SNP) | VAF 23/229 reads (10%) | called by muse, mutect2, varscan2
- CBLN4 | c.453G>T p.A151= | Silent (SNP) | VAF 55/559 reads (10%) | called by muse, mutect2, varscan2
- CCDC168 | c.14673G>A p.R4891= | Silent (SNP) | VAF 21/30 reads (70%) | called by muse, mutect2, varscan2
- CD84 | c.996C>T p.D332= (on ENST00000311224 / NM_001184879.2; = p.D315= on NM_003874.4) | Silent (SNP) | VAF 161/418 reads (39%) | called by muse, mutect2, varscan2
- CEP131 | c.1734G>T p.L578= (on ENST00000269392 / NM_001319228.2; = p.L575= on NM_014984.4) | Silent (SNP) | VAF 68/313 reads (22%) | called by muse, mutect2, varscan2
- CEP135 | c.861G>T p.L287= | Silent (SNP) | VAF 57/83 reads (69%) | called by muse, mutect2, varscan2
- CFAP221 | c.1032C>T p.D344= | Silent (SNP) | VAF 17/102 reads (17%) | called by muse, mutect2, varscan2
- CFAP46 | c.1251G>A p.L417= | Silent (SNP) | VAF 26/69 reads (38%) | catalogued as rs915842697; called by muse, mutect2, varscan2
- CFAP52 | c.1395C>A p.S465= | Silent (SNP) | VAF 39/485 reads (8%) | called by muse, mutect2
- CHAT | c.1116C>T p.S372= | Silent (SNP) | VAF 77/543 reads (14%) | called by muse, mutect2, varscan2
- CHRND | c.18G>C p.L6= | Silent (SNP) | VAF 15/131 reads (11%) | called by muse, mutect2
- CLDN2 | c.141C>T p.S47= | Silent (SNP) | VAF 10/158 reads (6%) | called by muse, mutect2
- COL11A1 | c.5119C>A p.R1707= | Silent (SNP) | VAF 74/159 reads (47%) | catalogued as rs757608461, COSV62179966, COSV62203151; called by muse, mutect2, varscan2
- COL12A1 | c.7311C>G p.S2437= | Silent (SNP) | VAF 28/271 reads (10%) | catalogued as COSV59400696; called by muse, mutect2, varscan2
- COL24A1 | c.2826T>A p.G942= | Silent (SNP) | VAF 25/133 reads (19%) | called by muse, mutect2, varscan2
- COL26A1 | c.516T>A p.T172= (on ENST00000313669 / NM_001278563.3; = p.T170= on NM_133457.4) | Silent (SNP) | VAF 15/177 reads (8%) | catalogued as COSV58119582; called by muse, mutect2
- COL9A2 | c.498G>T p.L166= | Silent (SNP) | VAF 136/224 reads (61%) | called by muse, mutect2, varscan2
- CPOX | c.390C>T p.F130= | Silent (SNP) | VAF 79/223 reads (35%) | called by muse, mutect2, varscan2
- CRB2 | c.2115C>A p.I705= | Silent (SNP) | VAF 61/148 reads (41%) | called by muse, mutect2, varscan2
- CSMD3 | c.9822A>T p.V3274= (on ENST00000297405 / NM_001363185.1; = p.V3105= on NM_052900.3) | Silent (SNP) | VAF 108/657 reads (16%) | catalogued as COSV52209229; called by muse, mutect2, varscan2
- CT47B1 | c.219C>G p.A73= | Silent (SNP) | VAF 435/465 reads (94%) | catalogued as COSV64891143; called by muse, mutect2, varscan2
- CTF1 | c.600G>A p.S200= | Silent (SNP) | VAF 78/225 reads (35%) | catalogued as rs1026759136; called by muse, mutect2, varscan2
- CUX2 | c.2187G>A p.E729= | Silent (SNP) | VAF 13/44 reads (30%) | called by muse, mutect2, varscan2
- CYP21A2 | c.237G>A p.E79= | Silent (SNP) | VAF 40/476 reads (8%) | catalogued as rs762330375, COSV64488926; called by muse, mutect2, varscan2
- DCAF4L2 | c.306C>A p.I102= | Silent (SNP) | VAF 99/409 reads (24%) | called by muse, mutect2, varscan2
- DDX39A | c.840C>G p.L280= | Silent (SNP) | VAF 24/66 reads (36%) | catalogued as COSV54391403; called by muse, mutect2, varscan2
- DIAPH1 | c.2205C>T p.G735= | Silent (SNP) | VAF 20/65 reads (31%) | called by muse, mutect2, varscan2
- DNAI2 | c.912G>T p.V304= | Silent (SNP) | VAF 377/499 reads (76%) | called by muse, mutect2, varscan2
- DOK6 | c.774C>A p.S258= | Silent (SNP) | VAF 111/121 reads (92%) | called by muse, mutect2, varscan2
- DYTN | c.1485T>A p.V495= | Silent (SNP) | VAF 151/869 reads (17%) | called by muse, mutect2, varscan2
- E2F1 | c.675T>C p.N225= | Silent (SNP) | VAF 17/344 reads (5%) | called by muse, mutect2
- ECE1 | c.207G>T p.L69= | Silent (SNP) | VAF 98/306 reads (32%) | called by muse, mutect2, varscan2
- EPHA1 | c.1737G>A p.Q579= | Silent (SNP) | VAF 20/183 reads (11%) | called by muse, varscan2
- ERBB4 | c.318T>A p.R106= | Silent (SNP) | VAF 70/558 reads (13%) | called by muse, mutect2, varscan2
- FAM120B | c.2616G>A p.Q872= | Silent (SNP) | VAF 55/225 reads (24%) | catalogued as COSV99379711; called by muse, mutect2, varscan2
- FAM120C | c.2929C>A p.R977= | Silent (SNP) | VAF 95/216 reads (44%) | called by muse, mutect2, varscan2
- FBXO28 | c.993T>A p.A331= | Silent (SNP) | VAF 46/316 reads (15%) | called by muse, mutect2, varscan2
- FCGBP | c.600G>T p.V200= | Silent (SNP) | VAF 152/155 reads (98%) | called by muse, mutect2, varscan2
- FCRL3 | c.1428C>T p.P476= | Silent (SNP) | VAF 141/226 reads (62%) | catalogued as rs1468155648, COSV100943017, COSV63840188; called by muse, mutect2, varscan2
- FCRLA | c.531C>T p.I177= (on ENST00000367959; = p.I154= on NM_032738.4) | Silent (SNP) | VAF 22/274 reads (8%) | catalogued as rs766930615; called by muse, mutect2
- FECH | c.456C>T p.P152= | Silent (SNP) | VAF 56/194 reads (29%) | called by muse, mutect2, varscan2
- FHL1 | c.420C>T p.S140= | Silent (SNP) | VAF 174/542 reads (32%) | called by muse, mutect2, varscan2
- FLG | c.8379C>T p.S2793= | Silent (SNP) | VAF 359/2234 reads (16%) | catalogued as rs747057114, COSV64240050, COSV64240779; called by muse, mutect2, varscan2
- FLNC | c.7761C>A p.P2587= | Silent (SNP) | VAF 134/262 reads (51%) | called by muse, varscan2
- FN3K | c.324A>C p.A108= | Silent (SNP) | VAF 95/1058 reads (9%) | called by muse, mutect2
- FSCB | c.924A>T p.A308= | Silent (SNP) | VAF 15/232 reads (6%) | called by muse, mutect2
- GALK1 | c.498C>T p.R166= | Silent (SNP) | VAF 60/235 reads (26%) | catalogued as rs763880577; called by muse, mutect2, varscan2
- GAS2L2 | c.417G>T p.V139= | Silent (SNP) | VAF 171/262 reads (65%) | catalogued as rs781922164; called by muse, mutect2, varscan2
- GAS8 | c.60G>T p.G20= | Silent (SNP) | VAF 57/230 reads (25%) | called by muse, mutect2, varscan2
- GIGYF2 | c.1269C>T p.P423= | Silent (SNP) | VAF 50/391 reads (13%) | catalogued as COSV101004208; called by muse, mutect2, varscan2
- GIPR | c.741C>T p.L247= | Silent (SNP) | VAF 126/2131 reads (6%) | catalogued as COSV99624748; called by muse, mutect2
- GMPPB | c.1008C>A p.L336= (on ENST00000308388 / NM_021971.4; = p.L363= on NM_013334.3) | Silent (SNP) | VAF 59/95 reads (62%) | called by muse, mutect2, varscan2
- GNAT1 | c.27G>A p.E9= | Silent (SNP) | VAF 57/200 reads (29%) | catalogued as COSV104372303; called by muse, mutect2, varscan2
- GRIP1 | c.3114G>A p.G1038= (on ENST00000359742 / NM_001379345.1; = p.G986= on NM_021150.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 398/513 reads (78%) | called by muse, mutect2, varscan2
- GRM6 | c.24G>A p.R8= | Silent (SNP) | VAF 39/60 reads (65%) | called by muse, mutect2, varscan2
- GSC | c.186G>A p.V62= | Silent (SNP) | VAF 160/241 reads (66%) | called by muse, mutect2, varscan2
- HELZ2 | c.3861G>C p.L1287= (on ENST00000467148 / NM_001037335.2; = p.L718= on NM_033405.3) | Silent (SNP) | VAF 49/231 reads (21%) | called by muse, mutect2, varscan2
- HEPACAM2 | c.528T>G p.T176= (on ENST00000394468 / NM_001039372.4; = p.T164= on NM_198151.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 254/403 reads (63%) | called by muse, mutect2, varscan2
- HMCN1 | c.11865T>A p.L3955= | Silent (SNP) | VAF 184/420 reads (44%) | called by muse, mutect2, varscan2
- HPS5 | c.690G>T p.G230= (on ENST00000349215 / NM_181507.2; = p.G116= on NM_007216.4) | Silent (SNP) | VAF 166/168 reads (99%) | catalogued as COSV62540412; called by muse, mutect2, varscan2
- IGF2BP1 | c.105C>G p.V35= | Silent (SNP) | VAF 46/297 reads (15%) | called by muse, mutect2, varscan2
- IGKV3-15 | c.204C>A p.I68= | Silent (SNP) | VAF 291/708 reads (41%) | catalogued as rs755211568; called by muse, mutect2, varscan2
- INSC | c.762C>A p.T254= | Silent (SNP) | VAF 88/102 reads (86%) | catalogued as COSV65412910; called by muse, mutect2
- IQSEC2 | c.756A>T p.P252= (on ENST00000642864 / NM_001111125.3; = p.P47= on NM_015075.2) | Silent (SNP) | VAF 30/53 reads (57%) | called by muse, mutect2, varscan2
- IRX1 | c.1392G>A p.L464= | Silent (SNP) | VAF 60/582 reads (10%) | called by muse, mutect2, varscan2
- ITPKB | c.2796C>G p.L932= | Silent (SNP) | VAF 31/208 reads (15%) | called by muse, mutect2, varscan2
- KDM4D | c.516A>T p.I172= | Silent (SNP) | VAF 300/304 reads (99%) | called by muse, mutect2, varscan2
- KIAA1217 | c.399G>T p.L133= | Silent (SNP) | VAF 38/74 reads (51%) | called by muse, mutect2, varscan2
- KIF16B | c.489G>T p.R163= | Silent (SNP) | VAF 32/61 reads (52%) | called by muse, mutect2, varscan2
- KIF26A | c.5646C>T p.V1882= | Silent (SNP) | VAF 9/42 reads (21%) | called by muse, varscan2
- KRT4 | c.582C>G p.V194= | Silent (SNP) | VAF 106/1042 reads (10%) | called by muse, mutect2, varscan2
- LBP | c.954C>G p.T318= | Silent (SNP) | VAF 174/444 reads (39%) | called by muse, mutect2, varscan2
- LEUTX | c.258T>G p.R86= | Silent (SNP) | VAF 239/249 reads (96%) | called by muse, mutect2, varscan2
- LRRIQ3 | c.1431G>A p.E477= | Silent (SNP) | VAF 32/83 reads (39%) | called by muse, mutect2, varscan2
- LRRN4 | c.1782G>T p.T594= | Silent (SNP) | VAF 9/23 reads (39%) | called by muse, mutect2, varscan2
- MADCAM1 | c.996G>T p.L332= | Silent (SNP) | VAF 109/186 reads (59%) | called by muse, mutect2, varscan2
- MAGEC3 | c.1845C>A p.A615= | Silent (SNP) | VAF 143/146 reads (98%) | catalogued as COSV100026254; called by muse, mutect2, varscan2
- MALRD1 | c.3582C>T p.L1194= | Silent (SNP) | VAF 24/120 reads (20%) | called by muse, mutect2, varscan2
- MAP3K15 | c.2553C>T p.F851= | Silent (SNP) | VAF 45/229 reads (20%) | called by muse, mutect2, varscan2
- MDN1 | c.6210G>T p.V2070= | Silent (SNP) | VAF 192/762 reads (25%) | called by muse, mutect2, varscan2
- MEAK7 | c.804G>T p.L268= | Silent (SNP) | VAF 145/235 reads (62%) | catalogued as COSV59145253; called by muse, mutect2, varscan2
- MED12 | c.5673C>A p.S1891= | Silent (SNP) | VAF 8/196 reads (4%) | called by muse, mutect2
- MEGF11 | c.285C>T p.S95= | Silent (SNP) | VAF 68/173 reads (39%) | catalogued as rs878944232, COSV99987805; called by muse, mutect2, varscan2
- MKRN3 | c.1275C>A p.G425= | Silent (SNP) | VAF 89/170 reads (52%) | called by muse, mutect2, varscan2
- MRPS21 | c.165A>G p.E55= | Silent (SNP) | VAF 10/152 reads (7%) | called by muse, mutect2
- MRTFA | c.1080C>T p.A360= | Silent (SNP) | VAF 116/188 reads (62%) | catalogued as rs1392573674, COSV62933382; called by muse, mutect2, varscan2
- MSR1 | c.636C>A p.I212= | Silent (SNP) | VAF 76/146 reads (52%) | called by muse, mutect2, varscan2
- MUC16 | c.6579C>A p.S2193= | Silent (SNP) | VAF 64/69 reads (93%) | called by muse, mutect2, varscan2
- MUC22 | c.300C>T p.D100= | Silent (SNP) | VAF 12/112 reads (11%) | called by muse, mutect2, varscan2
- MUCL3 | c.900C>A p.S300= | Silent (SNP) | VAF 291/468 reads (62%) | called by muse, mutect2, varscan2
- MYH13 | c.4104C>T p.A1368= | Silent (SNP) | VAF 80/691 reads (12%) | catalogued as rs377365193; called by muse, mutect2, varscan2
- MYO18B | c.6810G>T p.L2270= | Silent (SNP) | VAF 63/91 reads (69%) | called by muse, mutect2, varscan2
- MYOM2 | c.1086C>A p.G362= | Silent (SNP) | VAF 33/57 reads (58%) | catalogued as COSV50718277; called by muse, mutect2, varscan2
- NBEA | c.4857T>C p.H1619= | Silent (SNP) | VAF 60/86 reads (70%) | called by muse, mutect2, varscan2
- NLRP6 | c.1275C>T p.S425= | Silent (SNP) | VAF 20/234 reads (9%) | called by muse, mutect2
- NMBR | c.1060C>T p.L354= | Silent (SNP) | VAF 91/188 reads (48%) | called by muse, mutect2, varscan2
- NPRL3 | c.831C>T p.D277= (on ENST00000611875 / NM_001077350.3; = p.D252= on NM_001039476.2 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 33/139 reads (24%) | called by muse, mutect2, varscan2
- NTF4 | c.366C>A p.G122= | Silent (SNP) | VAF 98/154 reads (64%) | called by muse, varscan2
- NUTM1 | c.1308G>T p.L436= | Silent (SNP) | VAF 40/90 reads (44%) | catalogued as rs749670673; called by muse, mutect2, varscan2
- OAS2 | c.1902G>T p.V634= | Silent (SNP) | VAF 40/60 reads (67%) | called by mutect2, varscan2
- OR10G3 | c.837C>T p.A279= | Silent (SNP) | VAF 51/94 reads (54%) | called by muse, mutect2, varscan2
- OR10K1 | c.904C>A p.R302= | Silent (SNP) | VAF 83/211 reads (39%) | catalogued as COSV56870768, COSV99193382; called by muse, mutect2, varscan2
- OR10K2 | c.207T>A p.S69= | Silent (SNP) | VAF 220/436 reads (50%) | called by muse, mutect2, varscan2
- OR10X1 | c.180C>T p.I60= | Silent (SNP) | VAF 76/299 reads (25%) | catalogued as COSV100936618; called by muse, mutect2, varscan2
- OR1J4 | c.930C>A p.V310= | Silent (SNP) | VAF 38/67 reads (57%) | called by muse, mutect2, varscan2
- OR2T27 | c.213C>A p.I71= | Silent (SNP) | VAF 50/240 reads (21%) | called by muse, mutect2, varscan2
- OR4P4 | c.369C>T p.A123= | Silent (SNP) | VAF 31/61 reads (51%) | catalogued as rs1274808152; called by muse, mutect2, varscan2
- OR7E24 | c.927C>T p.S309= | Silent (SNP) | VAF 49/202 reads (24%) | called by muse, mutect2, varscan2
- OR9G4 | c.861T>C p.P287= | Silent (SNP) | VAF 57/191 reads (30%) | called by muse, mutect2, varscan2
- PAQR5 | c.723C>A p.R241= | Silent (SNP) | VAF 19/79 reads (24%) | called by muse, mutect2, varscan2
- PARK7 | c.303G>A p.L101= | Silent (SNP) | VAF 97/287 reads (34%) | called by muse, mutect2, varscan2
- PCDH10 | c.1800C>T p.L600= | Silent (SNP) | VAF 68/140 reads (49%) | catalogued as COSV99993195; called by muse, mutect2, varscan2
- PCDHA9 | c.474C>G p.S158= | Silent (SNP) | VAF 213/371 reads (57%) | catalogued as rs781916641, COSV65325536; called by muse, mutect2, varscan2
- PCDHGA10 | c.1548C>T p.G516= | Silent (SNP) | VAF 46/190 reads (24%) | catalogued as rs775890033; called by muse, mutect2, varscan2
- PCF11 | c.2871G>A p.E957= | Silent (SNP) | VAF 60/545 reads (11%) | called by muse, mutect2, varscan2
- PDCL | c.768G>A p.G256= | Silent (SNP) | VAF 30/166 reads (18%) | called by muse, mutect2, varscan2
- PDYN | c.366G>A p.L122= | Silent (SNP) | VAF 133/720 reads (18%) | called by muse, mutect2, varscan2
- PDZD2 | c.7455G>C p.L2485= | Silent (SNP) | VAF 41/411 reads (10%) | catalogued as COSV56854914; called by muse, mutect2, varscan2
- PGM5 | c.1518C>A p.I506= | Silent (SNP) | VAF 87/195 reads (45%) | called by muse, mutect2, varscan2
- PIGG | c.2799G>T p.T933= (on ENST00000453061 / NM_001127178.3; = p.T925= on NM_017733.4) | Silent (SNP) | VAF 23/84 reads (27%) | catalogued as COSV99573659; called by muse, mutect2, varscan2
- POU5F2 | c.81G>A p.L27= | Silent (SNP) | VAF 24/99 reads (24%) | called by muse, mutect2, varscan2
- PREX1 | c.3456C>A p.A1152= | Silent (SNP) | VAF 315/611 reads (52%) | called by muse, mutect2, varscan2
- PRR23B | c.738G>T p.A246= | Silent (SNP) | VAF 39/74 reads (53%) | catalogued as COSV61493405; called by muse, mutect2, varscan2
- PTCH2 | c.3135C>A p.G1045= | Silent (SNP) | VAF 139/361 reads (39%) | called by muse, mutect2, varscan2
- RANBP3 | c.618A>T p.A206= | Silent (SNP) | VAF 64/69 reads (93%) | called by muse, mutect2, varscan2
- RBFOX1 | c.159A>T p.T53= | Silent (SNP) | VAF 44/99 reads (44%) | called by muse, mutect2, varscan2
- RBM6 | c.810G>A p.R270= | Silent (SNP) | VAF 16/100 reads (16%) | called by muse, mutect2, varscan2
- REPS1 | c.525A>G p.P175= | Silent (SNP) | VAF 75/157 reads (48%) | called by muse, mutect2, varscan2
- RGPD3 | c.60G>T p.P20= | Silent (SNP) | VAF 74/436 reads (17%) | catalogued as rs778699719; called by muse, mutect2, varscan2
- RHBDF2 | c.2013C>T p.L671= | Silent (SNP) | VAF 13/119 reads (11%) | catalogued as rs777681843; called by muse, mutect2
- RIOK1 | c.1359G>A p.E453= | Silent (SNP) | VAF 20/258 reads (8%) | called by muse, mutect2
158 further variants in this file (0 protein-altering or splice-affecting, 46 silent, 112 other) are not listed here.
